Somatic mutation profile of tumor specimen TCGA-EA-A3HS-01A (aliquot TCGA-EA-A3HS-01A-11D-A20U-09) from TCGA case TCGA-EA-A3HS, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IB; Tumor grade: G1; Age at diagnosis: 35.9 years (13,117 days).
Specimen TCGA-EA-A3HS-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c7addada-0595-4931-b75f-3e54502ad7f3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EA-A3HS-10B (Blood Derived Normal), aliquot TCGA-EA-A3HS-10B-01D-A20U-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bf81db23-a848-4b47-a3bf-16a3d77fc720

The open-access MAF lists 804 somatic variants for this specimen: 621 protein-altering or splice-affecting, 168 silent, 15 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 537, Silent 168, Frame Shift Del 28, Nonsense Mutation 25, Frame Shift Ins 12, Splice Site 12, Intron 9, Splice Region 7, 3'Flank 2, RNA 2, 3'UTR 2.

Variants (750 of 804; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBXW7 | c.1972C>T p.R658* (on ENST00000281708 / NM_001349798.2; = p.R578* on NM_018315.5) | Nonsense Mutation (SNP) | VAF 35/49 reads (71%) | hotspot (GDC flag); catalogued as COSV55892162, COSV55908751; called by muse, mutect2, varscan2
- MSH6 | c.892C>T p.R298* | Nonsense Mutation (SNP) | VAF 10/17 reads (59%) | catalogued as rs146816935, COSV52281654; ClinVar: pathogenic; called by muse, varscan2
- PMPCA | c.1543G>A p.G515R | Missense Mutation (SNP) | VAF 37/80 reads (46%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs869025293, CM154755, COSV65510593; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SPAST | c.1378C>T p.R460C | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs878854990, CM042786, CM101457, COSV59518285; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AAMP | c.970G>A p.G324S | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT tolerated (0.15); PolyPhen benign (0.145); catalogued as rs766304750, COSV99816667; called by muse, varscan2
- AARS2 | c.2444C>T p.A815V | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs138828031; called by muse, mutect2, varscan2
- ABCG2 | c.661G>A p.A221T | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.751); catalogued as COSV99419970; called by muse, mutect2, varscan2
- AC098582.1 | c.3019G>A p.A1007T | Missense Mutation (SNP) | VAF 42/110 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99986105; called by muse, varscan2
- AC244197.3 | c.317C>T p.A106V | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.542); catalogued as COSV100558220; called by muse, mutect2, varscan2
- ACVR2A | c.285del p.D96Tfs*54 | Frame Shift Del (DEL) | VAF 11/26 reads (42%) | catalogued as rs1312707585, COSV54026507; called by mutect2, varscan2
- ADAM29 | c.932G>A p.R311H | Missense Mutation (SNP) | VAF 24/50 reads (48%) | SIFT tolerated (0.46); PolyPhen benign (0.007); catalogued as rs753780341, COSV63667689; called by muse, mutect2, varscan2
- ADAMTS18 | c.2875G>A p.V959M | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT tolerated (0.29); PolyPhen benign (0.101); catalogued as COSV99274545; called by muse, mutect2, varscan2
- ADAMTSL3 | c.3974-1G>T p.X1325_splice | Splice Site (SNP) | VAF 46/144 reads (32%) | catalogued as COSV54446136, COSV99718537; called by muse, mutect2, varscan2
- ADARB1 | c.2024G>A p.R675H (on ENST00000360697 / NM_001346687.2; = p.R635H on NM_001112.4) | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT deleterious (0.05); PolyPhen benign (0.178); catalogued as rs752123605, COSV62348616; called by muse, mutect2, varscan2
- ADCY6 | c.1417G>A p.V473M | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1433790319, COSV100326993; called by muse, mutect2, varscan2
- ADGRB2 | c.380G>A p.R127Q | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (0.34); PolyPhen benign (0.007); catalogued as rs372925356; called by muse, varscan2
- ADGRG4 | c.3184G>A p.A1062T | Missense Mutation (SNP) | VAF 28/81 reads (35%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as COSV99795669, COSV99797281; called by muse, mutect2, varscan2
- AFF2 | c.743C>T p.A248V | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.013); catalogued as rs782374220, COSV60675733; called by muse, mutect2, varscan2
- AFF3 | c.773G>A p.S258N | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT tolerated (0.33); PolyPhen benign (0.005); catalogued as COSV100420300; called by muse, mutect2, varscan2
- AGO4 | c.800G>A p.R267Q | Missense Mutation (SNP) | VAF 24/50 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.545); catalogued as COSV64617053; called by muse, mutect2, varscan2
- AKAP13 | c.6598C>T p.R2200C (on ENST00000394518 / NM_007200.5; = p.R2204C on NM_006738.6) | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63450117; called by muse, mutect2, varscan2
- AKAP9 | c.10176del p.K3392Nfs*62 (on ENST00000359028; = p.K3368Nfs*62 on NM_005751.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 17/34 reads (50%) | catalogued as COSV62360646; called by mutect2, pindel, varscan2
- ALAS2 | c.877C>T p.R293C | Missense Mutation (SNP) | VAF 52/150 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); catalogued as rs201086991, COSV100238716; called by muse, mutect2, varscan2
- ALDOB | c.991C>T p.R331W | Missense Mutation (SNP) | VAF 46/96 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs150407710; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ALPK2 | c.3343G>A p.D1115N | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.069); catalogued as COSV100864914; called by muse, mutect2, varscan2
- AMER1 | c.1252C>T p.R418W | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs372775016, COSV100366060; ClinVar: likely benign; called by muse, mutect2, varscan2
- AMOTL2 | c.1766C>T p.T589M | Missense Mutation (SNP) | VAF 16/136 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1436358578, COSV99850746; called by muse, mutect2, varscan2
- ANGPTL2 | c.816G>A p.S272= | Splice Region (SNP) | VAF 28/58 reads (48%) | catalogued as rs145108712, COSV99402760; called by muse, mutect2
- ANKFN1 | c.868A>G p.S290G | Missense Mutation (SNP) | VAF 25/51 reads (49%) | SIFT tolerated (0.17); PolyPhen benign (0.023); catalogued as COSV100594329; called by muse, mutect2, varscan2
- AOC1 | c.1697C>T p.A566V | Missense Mutation (SNP) | VAF 32/88 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.529); catalogued as COSV100711045; called by muse, mutect2, varscan2
- AP4E1 | c.632G>A p.R211Q | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.169); catalogued as rs750328226, COSV99957306; called by muse, mutect2, varscan2
- ARAF | c.289A>C p.T97P | Missense Mutation (SNP) | VAF 47/110 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); catalogued as COSV99283489; called by muse, mutect2, varscan2
- ARFGEF1 | c.4450C>G p.Q1484E | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as COSV99145429; called by muse, mutect2, varscan2
- ARHGAP27 | c.2140G>A p.V714M (on ENST00000428638 / NM_001282290.1; = p.V373M on NM_199282.3) | Missense Mutation (SNP) | VAF 16/26 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs747320660, COSV100976660; called by muse, varscan2
- ASXL3 | c.4180G>A p.A1394T | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.014); catalogued as COSV99326986; called by muse, mutect2, varscan2
- ATAD2B | c.1404del p.F468Lfs*9 | Frame Shift Del (DEL) | VAF 23/50 reads (46%) | catalogued as rs866490133; called by mutect2, pindel, varscan2
- ATF7IP | c.2326A>G p.I776V | Missense Mutation (SNP) | VAF 38/78 reads (49%) | SIFT tolerated, low confidence (0.9); PolyPhen benign (0.071); catalogued as COSV99662289; called by muse, mutect2, varscan2
- ATG2A | c.1483G>A p.V495M | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.959); catalogued as rs200574784, COSV101034908; called by muse, mutect2, varscan2
- ATP13A3 | c.3662C>T p.A1221V (on ENST00000645319 / NM_001367549.1; = p.A1191V on NM_024524.3) | Missense Mutation (SNP) | VAF 14/144 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.615); catalogued as rs773710020, COSV55465165; called by muse, mutect2
- ATP2B1 | c.2365C>T p.R789C | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as rs1161061134, COSV99665878; called by muse, mutect2, varscan2
- B3GNT8 | c.304G>A p.A102T | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT tolerated (0.33); PolyPhen benign (0.27); catalogued as rs758227092, COSV54195368; called by muse, mutect2, varscan2
- BAHCC1 | c.5996G>A p.R1999Q | Missense Mutation (SNP) | VAF 28/65 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.147); catalogued as rs371608192, COSV57035355; called by muse, mutect2, varscan2
- BCR | c.1249G>A p.D417N | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.158); catalogued as COSV100007180; called by muse, mutect2, varscan2
- BDKRB1 | c.694C>T p.R232W | Missense Mutation (SNP) | VAF 37/98 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); catalogued as rs371690606; called by muse, mutect2, varscan2
- BGN | c.388C>T p.H130Y | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.713); catalogued as COSV100525326; called by muse, varscan2
- BNC1 | c.1796G>A p.G599E | Missense Mutation (SNP) | VAF 20/108 reads (19%) | SIFT tolerated (0.59); PolyPhen benign (0.001); catalogued as COSV100597542; called by muse, mutect2, varscan2
- BPTF | c.1897G>A p.V633M | Missense Mutation (SNP) | VAF 15/26 reads (58%) | SIFT tolerated (0.14); PolyPhen benign (0.022); catalogued as rs139353057; called by muse, mutect2, varscan2
- BRSK1 | c.1726G>A p.A576T | Missense Mutation (SNP) | VAF 42/92 reads (46%) | SIFT tolerated (0.07); PolyPhen benign (0.019); catalogued as rs1355958794, COSV58670301; called by muse, mutect2, varscan2
- C16orf89 | c.580G>T p.G194C | Missense Mutation (SNP) | VAF 39/86 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100281007; called by muse, mutect2, varscan2
- CACNA1B | c.3092C>T p.T1031I | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT tolerated (0.28); PolyPhen benign (0.017); catalogued as rs1422328721, COSV99500411; called by muse, mutect2, varscan2
- CACNA1B | c.6298C>T p.R2100W | Missense Mutation (SNP) | VAF 11/18 reads (61%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.853); catalogued as rs537640912, COSV99500419; called by muse, varscan2
- CACNA1F | c.4342A>G p.T1448A | Missense Mutation (SNP) | VAF 27/59 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100545488; called by muse, mutect2, varscan2
- CALCOCO1 | c.176G>A p.R59Q | Missense Mutation (SNP) | VAF 35/83 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs759644053, COSV50419303; called by muse, mutect2, varscan2
- CAMK2A | c.829G>A p.V277M | Missense Mutation (SNP) | VAF 9/172 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV100652128; called by muse, mutect2
- CAMSAP3 | c.1136C>A p.S379Y | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.075); catalogued as COSV99352223; called by muse, mutect2, varscan2
- CAPN3 | c.2218G>A p.G740S | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.446); catalogued as rs398123145, COSV99783306; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CARMIL1 | c.2860G>A p.E954K | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.994); catalogued as rs558045301, COSV61515810; called by muse, mutect2, varscan2
- CARMIL3 | c.73G>A p.V25M | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.84); catalogued as rs750682495, COSV100549302; called by muse, mutect2, varscan2
- CARMIL3 | c.1480G>A p.D494N | Missense Mutation (SNP) | VAF 7/69 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.124); catalogued as rs755640779, COSV100549937; called by muse, mutect2, varscan2
- CASP9 | c.578G>A p.R193H | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs748271106, COSV100423775; called by muse, mutect2, varscan2
- CASZ1 | c.74G>A p.R25H | Missense Mutation (SNP) | VAF 7/110 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs1365430633; called by muse, mutect2
- CBLC | c.354-1G>T p.X118_splice | Splice Site (SNP) | VAF 7/42 reads (17%) | catalogued as COSV99542350; called by muse, mutect2, varscan2
- CBLN3 | c.70C>T p.L24F | Missense Mutation (SNP) | VAF 34/73 reads (47%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs773414234, COSV99250186; called by muse, mutect2, varscan2
- CCDC17 | c.956G>A p.R319Q | Missense Mutation (SNP) | VAF 42/90 reads (47%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs772631795, COSV100602046, COSV59648653; called by muse, mutect2
- CCDC33 | c.673G>T p.G225W | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100350809; called by muse, mutect2, varscan2
- CCDC88B | c.2420C>T p.A807V | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT tolerated (0.95); PolyPhen benign (0.383); catalogued as rs1202577643, COSV100106061; called by muse, mutect2, varscan2
- CCDC88B | c.3998del p.P1333Lfs*276 | Frame Shift Del (DEL) | VAF 4/22 reads (18%) | catalogued as rs35974392, COSV57267586; called by pindel, varscan2
- CCNB3 | c.2804A>C p.E935A | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.589); catalogued as COSV52070944, COSV99330034; called by muse, varscan2
- CCP110 | c.1471G>A p.A491T | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT tolerated (0.52); PolyPhen benign (0.001); catalogued as rs781615627, COSV66816671; called by muse, mutect2, varscan2
- CD276 | c.334G>A p.V112M | Missense Mutation (SNP) | VAF 44/118 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs141119771; called by muse, mutect2, varscan2
- CDC14A | c.375del p.Y126Ifs*64 | Frame Shift Del (DEL) | VAF 20/60 reads (33%) | catalogued as rs773911500; called by mutect2, pindel, varscan2
- CDC42BPA | c.3467G>A p.R1156Q (on ENST00000334218 / NM_001366019.2; = p.R1143Q on NM_003607.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.767); catalogued as rs373550338; called by muse, mutect2, varscan2
- CDC5L | c.2249G>A p.R750H | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs202064406, COSV65175259; called by muse, mutect2, varscan2
- CDH24 | c.1501G>A p.V501M | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.107); catalogued as rs757584877, COSV57460879; called by muse, mutect2
- CDH24 | c.844C>T p.R282W | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.713); catalogued as rs1185926925, COSV99400492; called by muse, mutect2, varscan2
- CEBPZ | c.2885-3del | Splice Region (DEL) | VAF 5/18 reads (28%) | catalogued as rs375852685; called by mutect2, varscan2
- CEBPZ | c.2485C>T p.R829W | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.852); catalogued as rs372639283; called by muse, mutect2, varscan2
- CEP135 | c.727C>T p.R243* | Nonsense Mutation (SNP) | VAF 15/36 reads (42%) | catalogued as rs200221082; called by muse, mutect2, varscan2
- CFAP157 | c.1552C>T p.R518C | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT tolerated (0.11); PolyPhen benign (0.431); catalogued as rs748804019, COSV100077133; called by muse, mutect2, varscan2
- CFAP206 | c.1085C>A p.P362H | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV99740207; called by muse, mutect2, varscan2
- CHD3 | c.1897G>A p.V633I | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as rs377213049; called by muse, mutect2, varscan2
- CHRDL2 | c.1121G>T p.G374V (on ENST00000376332 / NM_001304415.1; = p.Q392H on NM_015424.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs189131085, COSV99734166; called by mutect2, varscan2
- CILP2 | c.1916C>A p.T639N | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); catalogued as COSV99365302; called by muse, mutect2, varscan2
- CLASP1 | c.2791G>A p.D931N | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99757573; called by muse, mutect2, varscan2
- CLEC17A | c.66G>T p.E22D | Missense Mutation (SNP) | VAF 52/133 reads (39%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0.001); catalogued as rs1441236364, COSV60428417; called by muse, mutect2, varscan2
- CLEC4F | c.8G>A p.G3D | Missense Mutation (SNP) | VAF 32/65 reads (49%) | SIFT tolerated (0.15); PolyPhen benign (0.055); catalogued as COSV99714069; called by muse, mutect2, varscan2
- CLIP2 | c.1445C>T p.A482V | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as rs376115830, COSV99792222; called by muse, mutect2, varscan2
- CLIP3 | c.461C>T p.T154M | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.761); catalogued as rs779187288, COSV100859377; called by muse, mutect2, varscan2
- CNTNAP3 | c.3515G>A p.R1172H | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.013); catalogued as COSV52663446; called by muse, varscan2
- COL13A1 | c.1492G>A p.E498K (on ENST00000398978 / NM_001130103.2; = p.E441K on NM_080798.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.422); catalogued as COSV100637942; called by muse, mutect2
- COL27A1 | c.2501C>T p.P834L | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs147281917; called by muse, mutect2, varscan2
- COL4A6 | c.836C>T p.P279L | Missense Mutation (SNP) | VAF 29/61 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as rs761681684, COSV100565164; called by muse, mutect2, varscan2
- COL5A3 | c.908C>T p.T303M | Missense Mutation (SNP) | VAF 59/142 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs766094616, COSV53422840; called by muse, mutect2, varscan2
- COL7A1 | c.7036C>T p.R2346C | Missense Mutation (SNP) | VAF 36/53 reads (68%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.828); catalogued as rs145729761; called by muse, mutect2, varscan2
- COL8A1 | c.487C>T p.P163S | Missense Mutation (SNP) | VAF 32/87 reads (37%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.793); catalogued as COSV53735749; called by muse, mutect2, varscan2
- COX18 | c.752G>A p.R251H | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.035); catalogued as rs763271464, COSV55720888; called by muse, mutect2, varscan2
- CP | c.2750C>T p.A917V | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT tolerated (0.32); PolyPhen benign (0.022); catalogued as COSV99224554; called by muse, mutect2, varscan2
- CPAMD8 | c.2707C>T p.R903C (on ENST00000651564; = p.R856C on NM_015692.5) | Missense Mutation (SNP) | VAF 16/122 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.033); catalogued as rs369376971; called by muse, mutect2, varscan2
- CPNE7 | c.1133G>A p.G378D | Missense Mutation (SNP) | VAF 27/71 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as COSV52012601; called by muse, mutect2, varscan2
- CRKL | c.343G>T p.A115S | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT tolerated (0.45); PolyPhen benign (0.011); catalogued as rs1378195752, COSV100574190, COSV100574227; called by muse, mutect2, varscan2
- CSNK1A1L | c.598C>T p.R200C | Missense Mutation (SNP) | VAF 93/221 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs761422769, COSV101131136; called by muse, mutect2, varscan2
- CTNNA2 | c.368T>C p.M123T | Missense Mutation (SNP) | VAF 33/70 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.837); catalogued as COSV100786486; called by muse, mutect2, varscan2
- CUBN | c.3350C>T p.S1117L | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100913697; called by muse, mutect2, varscan2
- CYP3A7 | c.778C>T p.R260C | Missense Mutation (SNP) | VAF 28/54 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.591); catalogued as rs371807974; called by muse, mutect2, varscan2
- CYRIA | c.242C>T p.A81V | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT tolerated (0.15); PolyPhen benign (0.409); catalogued as rs775108109, COSV62867362; called by muse, mutect2, varscan2
- CYTH3 | c.760G>A p.D254N | Missense Mutation (SNP) | VAF 34/83 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.116); catalogued as COSV100641646; called by muse, mutect2, varscan2
- CYTH3 | c.658G>A p.A220T | Missense Mutation (SNP) | VAF 35/91 reads (38%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as rs749850896, COSV63438103; called by muse, mutect2, varscan2
- DCAF8 | c.956C>T p.A319V | Missense Mutation (SNP) | VAF 25/55 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.067); catalogued as rs1431324556, COSV58783170; called by muse, mutect2, varscan2
- DDX21 | c.1870G>A p.V624I | Missense Mutation (SNP) | VAF 28/59 reads (47%) | SIFT tolerated (0.88); PolyPhen benign (0.028); catalogued as rs754549618, COSV100826558; called by muse, mutect2, varscan2
- DDX27 | c.2072del p.K691Rfs*4 | Frame Shift Del (DEL) | VAF 20/53 reads (38%) | catalogued as rs766714372; called by mutect2, varscan2
- DEF6 | c.1249A>G p.K417E | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as COSV100359588; called by muse, mutect2, varscan2
- DEPDC5 | c.1814G>A p.R605Q | Missense Mutation (SNP) | VAF 28/69 reads (41%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.931); catalogued as rs760696765, COSV99834777; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DEPDC5 | c.3710G>A p.R1237Q (on ENST00000400246; = p.R1306Q on NM_014662.5) | Missense Mutation (SNP) | VAF 45/104 reads (43%) | SIFT tolerated (0.42); PolyPhen probably damaging (0.999); catalogued as rs1390184207, COSV99836813; called by muse, mutect2, varscan2
- DGLUCY | c.794G>A p.C265Y | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT tolerated (0.93); PolyPhen benign (0); catalogued as rs748707396, COSV99824840; called by muse, mutect2, varscan2
- DIP2B | c.2166T>A p.D722E | Missense Mutation (SNP) | VAF 29/65 reads (45%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.887); catalogued as COSV99999612; called by muse, mutect2, varscan2
- DIS3 | c.2164G>A p.A722T | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100900028; called by muse, mutect2, varscan2
- DLGAP2 | c.2006G>A p.S669N | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.981); catalogued as rs1273999890, COSV101422948; called by muse, mutect2, varscan2
- DLGAP2 | c.2263G>A p.G755R | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1262675720, COSV101422952, COSV101423006; called by muse, mutect2, varscan2
- DMBT1 | c.6680G>A p.R2227H (on ENST00000338354 / NM_001377530.1; = p.R1470H on NM_004406.3) | Missense Mutation (SNP) | VAF 31/70 reads (44%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.804); catalogued as rs769457915, COSV57542939; called by muse, mutect2, varscan2
- DMD | c.3912G>T p.E1304D | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.077); catalogued as COSV100823402; called by muse, mutect2, varscan2
- DNAH12 | c.276del p.G93Dfs*7 | Frame Shift Del (DEL) | VAF 17/21 reads (81%) | catalogued as rs751671358; called by mutect2, varscan2
- DNAH7 | c.2063G>A p.R688Q | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.9); catalogued as rs759632593, COSV100418030, COSV56774077; called by muse, mutect2, varscan2
- DNAH8 | c.10249G>A p.A3417T | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT tolerated (0.62); PolyPhen benign (0.003); catalogued as COSV100547403; called by muse, mutect2, varscan2
- DNAJA2 | c.235G>A p.G79S | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT tolerated (0.43); PolyPhen benign (0.015); catalogued as rs768986577, COSV57694334; called by muse, mutect2, varscan2
- DNMT1 | c.370G>C p.D124H | Missense Mutation (SNP) | VAF 42/99 reads (42%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.299); catalogued as COSV100533184; called by muse, mutect2, varscan2
- DOP1A | c.5353T>C p.S1785P | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.986); catalogued as COSV99383102; called by muse, mutect2, varscan2
- DRC3 | c.1186G>A p.E396K | Missense Mutation (SNP) | VAF 37/71 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.026); catalogued as rs748821348, COSV58261615; called by muse, mutect2, varscan2
- DST | c.7319C>T p.T2440M | Missense Mutation (SNP) | VAF 38/73 reads (52%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.001); catalogued as rs778324441, COSV99760808; called by muse, mutect2, varscan2
- DUSP10 | c.904G>A p.A302T | Missense Mutation (SNP) | VAF 20/35 reads (57%) | SIFT tolerated (0.25); PolyPhen benign (0.017); catalogued as rs751183346, COSV100100127; called by muse, mutect2, varscan2
- DYNC1I1 | c.1898C>T p.A633V | Missense Mutation (SNP) | VAF 40/78 reads (51%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as rs556401895, COSV100269514; called by muse, mutect2, varscan2
- DYRK2 | c.1447C>T p.R483W (on ENST00000344096 / NM_006482.3; = p.R410W on NM_003583.4) | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs748801595, COSV100165252; called by muse, mutect2, varscan2
- E2F1 | c.1303del p.L435Wfs*58 | Frame Shift Del (DEL) | VAF 32/87 reads (37%) | catalogued as rs1409099723, COSV55776265; called by mutect2, pindel, varscan2
- ECM1 | c.1083C>T p.A361= | Splice Region (SNP) | VAF 6/22 reads (27%) | catalogued as rs144607263; called by muse, varscan2
- EEF1AKNMT | c.1682G>C p.G561A (on ENST00000361735 / NM_015935.5; = p.G475A on NM_014955.3) | Missense Mutation (SNP) | VAF 57/93 reads (61%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as COSV100676084; called by muse, mutect2, varscan2
- EEF2KMT | c.527G>A p.C176Y | Missense Mutation (SNP) | VAF 57/252 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.078); catalogued as rs1467650646, COSV99276068; called by muse, mutect2, varscan2
- EFCAB5 | c.4226A>G p.Y1409C | Missense Mutation (SNP) | VAF 26/53 reads (49%) | SIFT tolerated (0.07); PolyPhen benign (0.029); catalogued as COSV100300921; called by muse, mutect2, varscan2
- EIF3A | c.2758C>T p.R920C | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); catalogued as rs780944947, COSV64960500; called by muse, mutect2
- EIF4A2 | c.556G>T p.D186Y | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99961410; called by muse, mutect2, varscan2
- EIF4E | c.182G>A p.R61Q | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0.145); catalogued as COSV55187633; called by muse, mutect2
- EIF4G2 | c.533G>A p.R178Q | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100379339, COSV60598890; called by muse, mutect2, varscan2
- EIF4H | c.211C>T p.R71W | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as COSV99733702; called by muse, mutect2, varscan2
- ELAVL3 | c.47del p.G16Afs*35 | Frame Shift Del (DEL) | VAF 20/50 reads (40%) | catalogued as rs751148694; called by mutect2, varscan2
- ELN | c.617A>T p.Y206F | Missense Mutation (SNP) | VAF 22/42 reads (52%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.98); catalogued as COSV52714170, COSV99333295; called by muse, mutect2, varscan2
- ELOVL6 | c.253A>G p.M85V | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.038); catalogued as COSV100165529; called by muse, mutect2, varscan2
- EPN2 | c.1162G>A p.A388T | Missense Mutation (SNP) | VAF 33/86 reads (38%) | SIFT tolerated (0.55); PolyPhen benign (0.031); catalogued as COSV100127784; called by muse, mutect2, varscan2
- ERP29 | c.484G>A p.D162N | Missense Mutation (SNP) | VAF 27/74 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.394); catalogued as rs201620890, COSV99923739; called by muse, mutect2, varscan2
- EXOC1 | c.146A>G p.Q49R | Missense Mutation (SNP) | VAF 21/36 reads (58%) | SIFT tolerated (0.56); PolyPhen benign (0.013); catalogued as COSV100638066; called by muse, mutect2, varscan2
- EXOSC1 | c.241C>T p.R81C | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as rs1184978489, COSV61749542; called by muse, mutect2
- F2 | c.103C>T p.R35W | Missense Mutation (SNP) | VAF 41/117 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.093); catalogued as rs144785536, COSV61314992; called by muse, mutect2, varscan2
- FADD | c.163C>A p.L55M | Missense Mutation (SNP) | VAF 26/53 reads (49%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.995); catalogued as COSV100096779; called by muse, mutect2, varscan2
- FAHD2B | c.842del p.P281Qfs*26 | Frame Shift Del (DEL) | VAF 34/84 reads (40%) | catalogued as rs751966944; called by mutect2, pindel, varscan2
- FAM120B | c.214C>T p.R72* | Nonsense Mutation (SNP) | VAF 9/80 reads (11%) | catalogued as rs771547946, COSV99380054; called by muse, mutect2, varscan2
- FAM20B | c.953C>T p.S318L | Missense Mutation (SNP) | VAF 10/108 reads (9%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as rs752917401, COSV99762679; called by muse, mutect2
- FAM47B | c.593G>A p.R198H | Missense Mutation (SNP) | VAF 39/102 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs554353244, COSV61454138; called by muse, mutect2, varscan2
- FAT3 | c.7525G>A p.V2509M | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.013); catalogued as rs972547916, COSV99972065; called by muse, mutect2, varscan2
- FBLN7 | c.1283C>T p.S428F | Missense Mutation (SNP) | VAF 37/78 reads (47%) | SIFT tolerated (0.21); PolyPhen benign (0.111); catalogued as COSV99735031; called by muse, mutect2, varscan2
- FBN2 | c.8515G>T p.G2839W | Missense Mutation (SNP) | VAF 17/104 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99331278; called by muse, mutect2, varscan2
- FBXL7 | c.733G>A p.V245M | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.851); catalogued as COSV100311106; called by muse, mutect2
- FCER2 | c.47G>A p.R16Q | Missense Mutation (SNP) | VAF 32/92 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.278); catalogued as rs765935864, COSV100689665; called by muse, mutect2
- FEM1A | c.1481C>T p.A494V | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT tolerated (0.43); PolyPhen benign (0.129); catalogued as COSV99521603; called by muse, mutect2, varscan2
- FEZ1 | c.940-1G>A p.X314_splice | Splice Site (SNP) | VAF 29/66 reads (44%) | catalogued as COSV99631308; called by muse, mutect2, varscan2
- FGF14 | c.305-1G>T p.X102_splice | Splice Site (SNP) | VAF 36/82 reads (44%) | catalogued as COSV101087987; called by muse, varscan2
- FGFRL1 | c.1358C>T p.P453L | Missense Mutation (SNP) | VAF 24/32 reads (75%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as rs755567722, COSV53258276; called by muse, mutect2, varscan2
- FHL3 | c.337C>T p.R113W | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs777013710, COSV100885166; called by muse, mutect2, varscan2
- FHOD3 | c.3304G>A p.A1102T (on ENST00000359247 / NM_001281739.3; = p.A1119T on NM_025135.5) | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99943428; called by muse, mutect2, varscan2
- FKBP15 | c.3137C>A p.P1046H | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.997); catalogued as COSV99439188, COSV99440118; called by muse, mutect2, varscan2
- FLCN | c.1724C>T p.S575L | Missense Mutation (SNP) | VAF 48/154 reads (31%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as rs763604691, COSV53259541; called by muse, mutect2, varscan2
- FLNA | c.5417-1G>T p.X1806_splice (on ENST00000369850 / NM_001110556.2; = p.X1798_splice on NM_001456.3) | Splice Site (SNP) | VAF 50/111 reads (45%) | catalogued as COSV100775357; called by muse, mutect2, varscan2
- FLT1 | c.3731G>A p.G1244D | Missense Mutation (SNP) | VAF 27/56 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs1315888360, COSV99169366; called by muse, mutect2, varscan2
- FLT4 | c.1003G>A p.V335I | Missense Mutation (SNP) | VAF 22/96 reads (23%) | SIFT tolerated (0.34); PolyPhen benign (0.017); catalogued as rs147644625, COSV99989418; called by muse, varscan2
- FMN2 | c.3552A>G p.I1184M | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.419); catalogued as COSV100147617; called by muse, mutect2, varscan2
- FMO1 | c.1505G>C p.R502P | Missense Mutation (SNP) | VAF 26/103 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100707987, COSV61446650; called by muse, mutect2, varscan2
- FNDC3B | c.25G>A p.D9N | Missense Mutation (SNP) | VAF 31/160 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.865); catalogued as rs780399563, COSV100395150; called by muse, mutect2, varscan2
- FOXO3 | c.730G>A p.G244R | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs1315303362, COSV100670273; called by muse, mutect2, varscan2
- FRMD5 | c.1178G>A p.R393H | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs148081959; called by muse, mutect2, varscan2
- FRMPD3 | c.3940C>T p.R1314C | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs752598751, COSV99347267; called by muse, mutect2, varscan2
- FRY | c.3076C>T p.R1026* | Nonsense Mutation (SNP) | VAF 10/32 reads (31%) | catalogued as COSV66569280; called by muse, mutect2, varscan2
- FRZB | c.433G>A p.G145S | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs151046356; called by muse, mutect2, varscan2
- FSHR | c.646G>A p.G216R | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100438154, COSV58635503; called by muse, mutect2, varscan2
- FSIP2 | c.18479C>G p.T6160S | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.99); catalogued as COSV100556863; called by muse, mutect2, varscan2
- FUCA2 | c.1361C>T p.P454L | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.573); catalogued as rs200632280, COSV99136285; called by muse, mutect2
- FYN | c.721C>T p.R241C | Missense Mutation (SNP) | VAF 26/59 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as rs760289292, COSV99992441; called by muse, mutect2, varscan2
- FZD10 | c.865G>A p.A289T | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV57473780; called by muse, mutect2, varscan2
- G6PD | c.1315C>T p.R439C | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100855164, COSV63702882; called by muse, mutect2, varscan2
- GABPB1 | c.739G>A p.A247T | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.57); PolyPhen probably damaging (0.971); catalogued as COSV99590218; called by muse, varscan2
- GANAB | c.2413C>T p.R805C | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1353779708, COSV99642125; called by muse, mutect2, varscan2
- GBA2 | c.595C>T p.Q199* | Nonsense Mutation (SNP) | VAF 20/39 reads (51%) | catalogued as COSV100803547; called by muse, mutect2, varscan2
- GCN1 | c.7178G>A p.R2393H | Missense Mutation (SNP) | VAF 28/65 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.212); catalogued as rs200245091, COSV56111400; called by muse, mutect2, varscan2
- GCNT1 | c.320G>A p.R107H | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.211); catalogued as rs142199715; called by muse, mutect2, varscan2
- GFAP | c.88C>T p.R30C | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.88); catalogued as rs770249831, COSV53648526; called by muse, mutect2, varscan2
- GIGYF2 | c.2339G>A p.R780Q | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.297); catalogued as rs754519471, COSV65254350, COSV65254603; called by muse, mutect2, varscan2
- GJB5 | c.343C>T p.R115C | Missense Mutation (SNP) | VAF 29/57 reads (51%) | SIFT deleterious (0.04); PolyPhen benign (0.009); catalogued as rs142097965, COSV58355493; called by muse, mutect2, varscan2
- GJD4 | c.941C>T p.P314L | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated (0.68); PolyPhen benign (0.005); catalogued as COSV100397381; called by muse, mutect2, varscan2
- GLI3 | c.2200G>A p.D734N | Missense Mutation (SNP) | VAF 50/101 reads (50%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as rs140479817; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GMEB1 | c.1340G>A p.R447H | Missense Mutation (SNP) | VAF 33/83 reads (40%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.662); catalogued as rs368023711; called by muse, mutect2, varscan2
- GNAZ | c.625C>T p.R209C | Missense Mutation (SNP) | VAF 24/96 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.554); catalogued as COSV99321308; called by muse, mutect2, varscan2
- GNS | c.223G>A p.G75R | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.15); catalogued as rs371990029; called by muse, mutect2, varscan2
- GPC4 | c.454G>A p.V152M | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.389); catalogued as COSV100895621; called by muse, mutect2, varscan2
- GPC6 | c.929C>T p.S310L | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.17); PolyPhen benign (0.053); catalogued as rs200811947, COSV100990180; called by muse, mutect2, varscan2
- GPCPD1 | c.1885C>T p.R629C | Missense Mutation (SNP) | VAF 18/28 reads (64%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.585); catalogued as rs185880154, COSV66832168; called by muse, varscan2
- GPR139 | c.649C>T p.R217C | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as rs942765597, COSV58501549; called by muse, mutect2, varscan2
- GPR143 | c.360G>A p.A120= | Splice Region (SNP) | VAF 14/43 reads (33%) | catalogued as rs281865178, CS983390, COSV101102322; ClinVar: not provided; called by muse, mutect2, varscan2
- GPR179 | c.248G>A p.R83H | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs765450066; called by muse, mutect2, varscan2
- GPSM1 | c.1807C>T p.L603F | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99396121; called by muse, mutect2, varscan2
- GRAMD1B | c.1507C>T p.R503C | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT tolerated (0.23); PolyPhen benign (0.014); catalogued as rs1331085646, COSV59202167; called by muse, mutect2, varscan2
- GRAMD4 | c.607G>A p.E203K | Missense Mutation (SNP) | VAF 44/135 reads (33%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.874); catalogued as COSV100730691; called by muse, mutect2, varscan2
- GRAP2 | c.830G>A p.R277Q | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT tolerated (0.07); PolyPhen benign (0.02); catalogued as rs202203713; called by muse, mutect2, varscan2
- GRHL1 | c.1796C>T p.T599I | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100258265; called by muse, mutect2, varscan2
- GRIA1 | c.1495C>T p.R499W | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs977210512, COSV53607087; called by muse, mutect2, varscan2
- GRIPAP1 | c.697G>A p.E233K | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.373); catalogued as COSV64552540; called by muse, mutect2, varscan2
- GRK3 | c.1292G>A p.R431Q | Missense Mutation (SNP) | VAF 25/63 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as rs774455287, COSV60793575, COSV60798794; called by muse, mutect2, varscan2
- GRM7 | c.2427del p.F809Lfs*21 | Frame Shift Del (DEL) | VAF 16/20 reads (80%) | catalogued as rs747773579; called by mutect2, varscan2
- GRM8 | c.1855C>T p.R619C | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs767201811, COSV58802360; called by muse, mutect2, varscan2
- GTF2H3 | c.644T>C p.L215P | Missense Mutation (SNP) | VAF 33/68 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1357654293, COSV57459623; called by muse, mutect2, varscan2
- HAUS6 | c.1588del p.S530Vfs*12 | Frame Shift Del (DEL) | VAF 18/49 reads (37%) | catalogued as rs34558496; called by mutect2, pindel, varscan2
- HCAR2 | c.665G>A p.R222Q | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT tolerated (0.2); PolyPhen benign (0.312); catalogued as rs769715682, COSV100186674; called by muse, mutect2, varscan2
- HCRTR2 | c.1193G>A p.R398Q | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.866); catalogued as rs1176698482, COSV63796137; called by muse, mutect2, varscan2
- HERC1 | c.10478C>T p.S3493F | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.49); PolyPhen benign (0.058); catalogued as COSV101496620; called by muse, mutect2, varscan2
- HERC2 | c.1462C>T p.Q488* | Nonsense Mutation (SNP) | VAF 21/46 reads (46%) | catalogued as COSV99877441; called by muse, mutect2, varscan2
- HERC5 | c.1571C>T p.S524L | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as rs766394501, COSV52043877; called by muse, mutect2, varscan2
- HIVEP3 | c.5254G>T p.G1752W | Missense Mutation (SNP) | VAF 42/102 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99914252; called by muse, varscan2
- HK1 | c.691G>A p.G231S | Missense Mutation (SNP) | VAF 60/142 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100066895, COSV100068192; called by muse, mutect2, varscan2
- HSPA1L | c.1030C>T p.R344C | Missense Mutation (SNP) | VAF 30/75 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.041); catalogued as rs544557163, COSV100989465; called by muse, mutect2, varscan2
- HSPG2 | c.1870C>T p.R624C | Missense Mutation (SNP) | VAF 42/92 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs779022485, COSV101021383; called by muse, mutect2, varscan2
- HTR1A | c.1262G>A p.R421H | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as COSV60500357; called by muse, mutect2, varscan2
- HTR1A | c.134C>T p.T45M | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT tolerated (0.26); PolyPhen benign (0.009); catalogued as COSV60502818; called by muse, mutect2
- HTR1B | c.563G>A p.R188H | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64051581; called by muse, mutect2, varscan2
- ICAM5 | c.1468G>A p.A490T | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.716); catalogued as COSV99703583; called by muse, mutect2, varscan2
- IFT140 | c.4339G>A p.A1447T | Missense Mutation (SNP) | VAF 18/101 reads (18%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as rs755962676, COSV51982188; called by muse, mutect2, varscan2
- IGF2BP3 | c.868C>T p.R290C | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.665); catalogued as rs894328352, COSV51685795; called by muse, mutect2, varscan2
- IL20 | c.408G>T p.E136D | Missense Mutation (SNP) | VAF 41/99 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.6); catalogued as COSV65585204; called by muse, mutect2, varscan2
- ILK | c.722G>A p.R241Q | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.21); catalogued as rs773215648, COSV100196686; called by muse, mutect2, varscan2
- ING1 | c.1102G>A p.G368S | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.953); catalogued as COSV100312452, COSV58171112; called by muse, mutect2, varscan2
- INPP5D | c.3224G>A p.G1075D (on ENST00000445964 / NM_001017915.3; = p.G1074D on NM_005541.5) | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.154); catalogued as rs759195359, COSV100856999; called by muse, mutect2, varscan2
- INSC | c.1072G>A p.V358I | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs552439006, COSV65409276; called by muse, mutect2, varscan2
- INTS1 | c.796G>A p.V266M | Missense Mutation (SNP) | VAF 30/71 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs780546769, COSV101248428; called by muse, mutect2, varscan2
- ITM2A | c.682C>T p.R228C | Missense Mutation (SNP) | VAF 32/71 reads (45%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.446); catalogued as rs750269782, COSV100964417, COSV64811207; called by muse, varscan2
- ITSN1 | c.1584G>T p.Q528H | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); catalogued as COSV101180637; called by muse, mutect2, varscan2
- ITSN2 | c.4622C>T p.A1541V | Missense Mutation (SNP) | VAF 34/68 reads (50%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs371101764; called by muse, mutect2, varscan2
- JPH2 | c.1989G>T p.E663D | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV100881804; called by muse, mutect2
- KALRN | c.4471C>T p.R1491W | Missense Mutation (SNP) | VAF 38/56 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs781157532, COSV99567757; called by muse, varscan2
- KCNC1 | c.62C>T p.T21M | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99789307; called by mutect2, varscan2
- KCNE3 | c.49G>A p.V17M | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT tolerated, low confidence (0.22); PolyPhen probably damaging (0.996); catalogued as rs773287275, CM085480, COSV100035579; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KCNQ2 | c.478C>T p.R160W | Missense Mutation (SNP) | VAF 42/106 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60440364; called by muse, varscan2
- KCNQ2 | c.458G>A p.R153Q | Missense Mutation (SNP) | VAF 48/108 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100610648, COSV60436325; called by muse, varscan2
- KCNS2 | c.1282C>T p.R428C | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.683); catalogued as rs770948960, COSV99751487; called by muse, varscan2
- KDM1B | c.1105G>A p.V369M (on ENST00000449850; = p.V237M on NM_153042.4) | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated (0.05); PolyPhen benign (0.103); catalogued as rs750152791, COSV52810351; called by muse, mutect2, varscan2
- KDM6B | c.2962C>T p.R988W | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.948); catalogued as rs970486254, COSV99642469; called by muse, mutect2, varscan2
- KIAA1109 | c.10856G>A p.S3619N | Missense Mutation (SNP) | VAF 14/20 reads (70%) | SIFT deleterious (0); PolyPhen benign (0.056); catalogued as rs1428805558, COSV99185485; called by muse, mutect2, varscan2
- KIF13B | c.5374G>A p.A1792T | Missense Mutation (SNP) | VAF 36/68 reads (53%) | SIFT tolerated (0.3); PolyPhen benign (0.009); catalogued as rs192432763, COSV101342289; called by muse, mutect2, varscan2
- KIR3DL2 | c.295C>T p.R99C | Missense Mutation (SNP) | VAF 67/144 reads (47%) | SIFT tolerated (0.07); PolyPhen benign (0.009); catalogued as rs376049512, COSV54390025; called by muse, mutect2, varscan2
- KL | c.364G>A p.G122R | Missense Mutation (SNP) | VAF 21/37 reads (57%) | SIFT tolerated (0.06); PolyPhen benign (0.124); catalogued as rs1481980429, COSV101199238; called by muse, mutect2, varscan2
- KLC2 | c.145G>C p.E49Q | Missense Mutation (SNP) | VAF 42/88 reads (48%) | SIFT tolerated (0.31); PolyPhen benign (0.02); catalogued as COSV100385267, COSV57582504, COSV57583573; called by muse, mutect2, varscan2
- KLF7 | c.580G>A p.V194I | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs199543928, COSV100519038; called by muse, mutect2, varscan2
- KLHL1 | c.381G>T p.E127D | Missense Mutation (SNP) | VAF 46/121 reads (38%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.031); catalogued as COSV100918324; called by muse, mutect2, varscan2
- KMT2C | c.9308C>T p.A3103V | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1295108695, COSV100077730; called by muse, mutect2, varscan2
- KMT2C | c.7825C>T p.R2609* | Nonsense Mutation (SNP) | VAF 46/105 reads (44%) | catalogued as COSV51419035; called by muse, varscan2
- KMT2D | c.13432C>T p.R4478W | Missense Mutation (SNP) | VAF 29/69 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.482); catalogued as rs562043836, COSV56497566, COSV99983233; called by muse, varscan2
- KMT2D | c.5089G>T p.G1697C | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99986444; called by muse, mutect2, varscan2
- LCA5 | c.1599A>C p.K533N | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.018); catalogued as COSV100878390; called by muse, mutect2, varscan2
- LCMT2 | c.1249C>T p.R417C | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs1466855643, COSV99980290; called by muse, mutect2, varscan2
- LHX1 | c.1194dup p.E399Rfs*65 | Frame Shift Ins (INS) | VAF 13/29 reads (45%) | catalogued as rs775423572; called by mutect2, varscan2
- LHX6 | c.796T>C p.W266R (on ENST00000373755 / NM_001242334.2; = p.W295R on NM_014368.5) | Missense Mutation (SNP) | VAF 14/21 reads (67%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.971); catalogued as COSV100493633; called by muse, mutect2, varscan2
- LIN7A | c.676C>T p.Q226* | Nonsense Mutation (SNP) | VAF 15/27 reads (56%) | catalogued as COSV99692821; called by muse, mutect2, varscan2
- LIPE | c.1034C>T p.A345V | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.996); catalogued as rs763240801, COSV99734485; called by muse, varscan2
- LOX | c.1010G>A p.R337Q | Missense Mutation (SNP) | VAF 39/99 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as COSV50239356; called by muse, mutect2, varscan2
- LRFN4 | c.1859G>A p.C620Y | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.447); catalogued as COSV100540918; called by muse, mutect2, varscan2
- LRIT1 | c.1138G>A p.A380T | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT tolerated (0.23); PolyPhen benign (0.178); catalogued as COSV100928179; called by muse, mutect2, varscan2
- LRP1 | c.2331del p.T778Lfs*2 | Frame Shift Del (DEL) | VAF 6/54 reads (11%) | catalogued as rs34108076; called by mutect2, pindel, varscan2
- LRP1B | c.7535C>A p.A2512D | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT tolerated (0.57); PolyPhen benign (0.001); catalogued as COSV101260114; called by muse, mutect2, varscan2
- LRP8 | c.2110T>C p.C704R | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100037032; called by muse, mutect2, varscan2
- LRRC47 | c.665C>T p.A222V | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.866); catalogued as rs750487355, COSV65562031; called by muse, mutect2, varscan2
- LYST | c.9839G>A p.R3280Q | Missense Mutation (SNP) | VAF 24/46 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs368573685, COSV67703899, COSV67704519; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MAB21L1 | c.749G>A p.C250Y | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV100084908; called by muse, mutect2, varscan2
- MAD1L1 | c.1666C>T p.R556C | Missense Mutation (SNP) | VAF 27/58 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.622); catalogued as rs371561369; called by muse, mutect2, varscan2
- MADCAM1 | c.872G>A p.R291H | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.57); PolyPhen benign (0.051); catalogued as rs747439523, COSV53128890; called by muse, mutect2, varscan2
- MAGI2 | c.2527G>A p.D843N | Missense Mutation (SNP) | VAF 53/127 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.736); catalogued as rs745367148, COSV62664020; called by muse, mutect2, varscan2
- MAML3 | c.2953G>T p.G985C | Missense Mutation (SNP) | VAF 45/64 reads (70%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.817); catalogued as COSV101558560, COSV72208474; called by muse, mutect2, varscan2
- MAN2B1 | c.1527C>T p.R509= | Splice Region (SNP) | VAF 11/25 reads (44%) | catalogued as rs1486751691, COSV99667246; called by muse, mutect2, varscan2
- MAP1B | c.6638G>A p.R2213H | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.854); catalogued as rs754794035, COSV57100897; called by muse, mutect2, varscan2
- MAP2K1 | c.770C>T p.A257V | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.274); catalogued as rs1334665647, COSV61072123; called by muse, mutect2, varscan2
- MAPRE3 | c.10A>G p.N4D | Missense Mutation (SNP) | VAF 27/79 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV99252062; called by muse, mutect2, varscan2
- MDC1 | c.1213G>T p.D405Y | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100903134; called by muse, mutect2, varscan2
- MDN1 | c.4488A>C p.K1496N | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as COSV101021912; called by muse, mutect2, varscan2
- MED12 | c.1570G>A p.V524M | Missense Mutation (SNP) | VAF 21/40 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV100380319; called by muse, mutect2, varscan2
- MEGF10 | c.269G>A p.R90H | Missense Mutation (SNP) | VAF 32/164 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs778835131, COSV57245863; called by muse, mutect2, varscan2
- MEGF8 | c.6443G>A p.G2148D (on ENST00000251268 / NM_001271938.2; = p.G2081D on NM_001410.3) | Missense Mutation (SNP) | VAF 20/41 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99239594; called by muse, mutect2, varscan2
- MIA2 | c.220C>T p.R74* | Nonsense Mutation (SNP) | VAF 5/29 reads (17%) | catalogued as rs1198250178, COSV54488632, COSV54498701; called by muse, mutect2, varscan2
- MKI67 | c.9629C>T p.A3210V | Missense Mutation (SNP) | VAF 46/118 reads (39%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.111); catalogued as COSV100897064; called by muse, mutect2
- MLLT11 | c.187G>T p.G63C | Missense Mutation (SNP) | VAF 37/56 reads (66%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.891); catalogued as COSV100927415, COSV100927420; called by muse, mutect2, varscan2
- MLST8 | c.706G>A p.A236T | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); catalogued as rs1313576548, COSV100064123; called by muse, mutect2, varscan2
- MPHOSPH9 | c.3484C>T p.R1162* | Nonsense Mutation (SNP) | VAF 13/23 reads (57%) | catalogued as rs757482974, COSV100187357; called by muse, varscan2
- MPP7 | c.241G>A p.E81K | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.597); catalogued as rs142463330, COSV100518036; called by muse, mutect2, varscan2
- MROH1 | c.446G>A p.S149N | Missense Mutation (SNP) | VAF 53/139 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1385152353, COSV100396210; called by muse, mutect2, varscan2
- MRPS22 | c.28C>A p.L10M | Missense Mutation (SNP) | VAF 26/139 reads (19%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.023); catalogued as COSV100169246; called by muse, mutect2, varscan2
- MRTFA | c.676G>A p.E226K | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); catalogued as rs138116355; called by muse, mutect2, varscan2
- MSI1 | c.362C>T p.T121M | Missense Mutation (SNP) | VAF 14/93 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs149956156; called by muse, mutect2, varscan2
- MTBP | c.2578C>T p.R860C | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs974620841, COSV100012640; called by muse, mutect2, varscan2
- MTMR7 | c.274G>A p.D92N | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.013); catalogued as rs527918462, COSV51666394; called by muse, mutect2, varscan2
- MUC5B | c.6893C>T p.P2298L | Missense Mutation (SNP) | VAF 76/203 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.09); catalogued as rs1400293940, COSV101500889, COSV71590937; called by muse, mutect2, varscan2
- MYCBP2 | c.6719A>T p.D2240V (on ENST00000357337; = p.D2278V on NM_015057.5) | Missense Mutation (SNP) | VAF 15/29 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100632318; called by muse, mutect2, varscan2
- MYH15 | c.5570G>A p.R1857Q | Missense Mutation (SNP) | VAF 23/127 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs576556260, COSV99841823; called by muse, mutect2, varscan2
- MYH3 | c.2363G>A p.R788Q | Missense Mutation (SNP) | VAF 35/81 reads (43%) | SIFT tolerated (0.18); PolyPhen benign (0.029); catalogued as rs747794027, COSV99879043; called by muse, mutect2, varscan2
- MYH6 | c.5140C>T p.R1714W | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs140651265, COSV62453761; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYH7 | c.5536C>T p.R1846C | Missense Mutation (SNP) | VAF 33/88 reads (38%) | SIFT tolerated (0.12); PolyPhen probably damaging (1); catalogued as rs12590294, CM109197; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYO18A | c.4936C>T p.R1646W | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs200860055; called by muse, mutect2, varscan2
- MYORG | c.865G>A p.V289I | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated (0.27); PolyPhen benign (0.005); catalogued as COSV99898897; called by muse, mutect2
- NAGLU | c.2125G>A p.V709I | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT tolerated (0.43); PolyPhen benign (0.012); catalogued as rs781410675, COSV56795690; called by muse, mutect2, varscan2
- NALCN | c.3995T>C p.M1332T | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.739); catalogued as COSV51951614; called by muse, mutect2, varscan2
- NAT10 | c.2063G>A p.R688Q | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs527894514, COSV99140616; called by muse, mutect2, varscan2
- NAV3 | c.2025T>C p.G675= | Splice Region (SNP) | VAF 14/32 reads (44%) | catalogued as rs1259202722, COSV99896543; called by muse, mutect2, varscan2
- NDUFAF6 | c.932C>T p.P311L | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.619); catalogued as rs1430891827, COSV99712554; called by muse, mutect2, varscan2
- NDUFC2 | c.175C>T p.R59C | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs147426758; called by muse, mutect2, varscan2
- NEK1 | c.1813dup p.I605Nfs*28 | Frame Shift Ins (INS) | VAF 14/30 reads (47%) | catalogued as rs1461849431; called by mutect2, varscan2
- NEO1 | c.1373C>T p.T458M | Missense Mutation (SNP) | VAF 41/92 reads (45%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.872); catalogued as rs142333707; called by muse, mutect2, varscan2
- NEUROG3 | c.376C>T p.R126C | Missense Mutation (SNP) | VAF 25/100 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99653437; called by muse, mutect2, varscan2
- NGLY1 | c.1756C>T p.R586* | Nonsense Mutation (SNP) | VAF 16/20 reads (80%) | catalogued as rs1383370693, COSV99770971; called by muse, mutect2, varscan2
- NIPBL | c.5366G>A p.R1789Q | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs80358380, CM042516, COSV56942266, COSV56950421; ClinVar: conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- NLRC4 | c.167A>G p.H56R | Missense Mutation (SNP) | VAF 18/30 reads (60%) | SIFT tolerated (0.13); PolyPhen benign (0.229); catalogued as COSV100707528; called by muse, mutect2, varscan2
- NLRP1 | c.1124C>A p.S375Y | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT tolerated (0.72); PolyPhen benign (0.029); catalogued as COSV99335763; called by muse, mutect2, varscan2
- NOL6 | c.1939G>T p.G647C | Missense Mutation (SNP) | VAF 65/149 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.421); catalogued as rs752592088, COSV99955305; called by muse, mutect2, varscan2
- NOMO3 | c.305C>T p.P102L | Missense Mutation (SNP) | VAF 34/150 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs534715930, COSV99531002; called by muse, mutect2, varscan2
- NPFFR2 | c.569C>T p.A190V | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs749031170, COSV100441431, COSV58146650; called by muse, mutect2, varscan2
- NPHP1 | c.1222C>T p.R408C (on ENST00000393272 / NM_207181.4; = p.R409C on NM_000272.5) | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs753700300, COSV57209901; called by muse, mutect2, varscan2
- NRCAM | c.2359C>T p.R787C (on ENST00000379028 / NM_001371124.1; = p.R771C on NM_005010.4 and 21 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs769341831, COSV61043555; called by muse, mutect2, varscan2
- NSA2 | c.685C>A p.L229I | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.209); catalogued as rs368758562; called by muse, mutect2, varscan2
- NTRK1 | c.2051G>C p.G684A | Missense Mutation (SNP) | VAF 73/116 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100693862; called by muse, mutect2, varscan2
- NTRK3 | c.1150C>A p.L384M | Missense Mutation (SNP) | VAF 51/147 reads (35%) | SIFT deleterious (0.05); PolyPhen benign (0.285); catalogued as COSV58115018; called by muse, mutect2, varscan2
- NUDT8 | c.643C>T p.R215C | Missense Mutation (SNP) | VAF 33/78 reads (42%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.012); catalogued as rs569654818, COSV100039964; called by muse, mutect2, varscan2
- NUMB | c.874C>T p.R292C (on ENST00000355058; = p.R281C on NM_003744.5) | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs774508876, COSV61828103; called by muse, mutect2, varscan2
- NUP160 | c.1390C>T p.P464S | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); catalogued as COSV101021675; called by muse, mutect2, varscan2
- NUP62 | c.1543C>T p.R515C | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.948); catalogued as rs1275705829, COSV100351859; called by muse, mutect2, varscan2
- NWD1 | c.3322C>T p.R1108W | Missense Mutation (SNP) | VAF 31/72 reads (43%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.928); catalogued as rs779720780, COSV100343903; called by muse, mutect2, varscan2
- NXPH2 | c.200A>G p.K67R | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as COSV99741410; called by muse, mutect2, varscan2
- OCIAD1 | c.465G>A p.M155I | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT tolerated (0.18); PolyPhen benign (0.005); catalogued as COSV99971304; called by muse, mutect2, varscan2
- OR10H5 | c.277G>A p.A93T | Missense Mutation (SNP) | VAF 25/200 reads (13%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as rs144286891; called by muse, mutect2, varscan2
- OR1A1 | c.640A>G p.I214V | Missense Mutation (SNP) | VAF 19/125 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0.014); catalogued as rs772589517, COSV100410856; called by muse, mutect2, varscan2
- OR4K2 | c.226T>G p.F76V | Missense Mutation (SNP) | VAF 20/146 reads (14%) | SIFT tolerated (0.61); PolyPhen probably damaging (0.979); catalogued as COSV100064818; called by muse, mutect2, varscan2
- OR52R1 | c.110C>T p.T37M | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs766625322, COSV100617813; called by muse, mutect2, varscan2
- OR5M10 | c.538G>A p.A180T | Missense Mutation (SNP) | VAF 27/61 reads (44%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.595); catalogued as rs566095437, COSV73242337; called by muse, mutect2, varscan2
- OR5M10 | c.316G>A p.A106T | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT tolerated (0.45); PolyPhen benign (0.012); catalogued as rs763236258, COSV73242390; called by muse, varscan2
- OSBPL9 | c.1234G>A p.A412T | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.25); catalogued as COSV100544191; called by muse, mutect2, varscan2
- PABPC3 | c.266G>A p.R89H | Missense Mutation (SNP) | VAF 34/70 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.466); catalogued as rs139240859; called by muse, varscan2
- PAPPA2 | c.2699G>A p.R900Q | Missense Mutation (SNP) | VAF 87/138 reads (63%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as rs570081516, COSV62781924; called by muse, mutect2, varscan2
- PARD3B | c.2509del p.T837Rfs*13 (on ENST00000406610 / NM_001302769.2; = p.T768Rfs*13 on NM_057177.7) | Frame Shift Del (DEL) | VAF 9/26 reads (35%) | catalogued as rs772816756; called by mutect2, pindel, varscan2
- PAX9 | c.1000C>T p.H334Y | Missense Mutation (SNP) | VAF 27/62 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.221); catalogued as COSV100492783; called by muse, mutect2, varscan2
- PCDHB1 | c.187G>A p.G63R | Missense Mutation (SNP) | VAF 32/66 reads (48%) | SIFT tolerated (0.38); PolyPhen benign (0.17); catalogued as rs1438180524, COSV100128137, COSV100128376; called by muse, mutect2, varscan2
- PCDHB10 | c.796G>A p.A266T | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as COSV53375482; called by muse, mutect2, varscan2
- PCDHB7 | c.1592T>C p.V531A | Missense Mutation (SNP) | VAF 90/254 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.9); catalogued as COSV50760070, COSV99177544; called by muse, mutect2, varscan2
- PCDHGA4 | c.424G>C p.E142Q | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.731); catalogued as COSV99542936; called by muse, mutect2, varscan2
- PCDHGB1 | c.311A>G p.E104G | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as rs1488535360, COSV99548812; called by muse, mutect2, varscan2
- PCDHGB1 | c.1876C>T p.R626C | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99548815; called by muse, mutect2, varscan2
- PCDHGC3 | c.2230G>A p.A744T | Missense Mutation (SNP) | VAF 27/54 reads (50%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV52747332, COSV99342804; called by muse, mutect2, varscan2
- PCDHGC4 | c.145G>A p.A49T | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs1318256454, COSV52777926; called by muse, mutect2, varscan2
- PCNT | c.8642G>A p.R2881Q | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.036); catalogued as rs753972547, COSV64027182; called by muse, mutect2
- PDZD2 | c.7415C>T p.T2472M | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.212); catalogued as rs753343462, COSV56861182; called by muse, mutect2, varscan2
- PDZD7 | c.157G>T p.G53W | Missense Mutation (SNP) | VAF 91/212 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs778664043, COSV99827616; called by muse, mutect2, varscan2
- PDZRN4 | c.1007C>T p.T336M (on ENST00000402685 / NM_001164595.2; = p.T78M on NM_013377.4) | Missense Mutation (SNP) | VAF 42/97 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs549596773, COSV100114809; called by muse, mutect2, varscan2
- PEDS1 | c.761C>T p.T254M | Missense Mutation (SNP) | VAF 16/106 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs201575410; called by muse, mutect2, varscan2
- PGM1 | c.1312G>A p.A438T | Missense Mutation (SNP) | VAF 15/101 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.253); catalogued as rs201303497, COSV64301589; called by muse, mutect2, varscan2
- PHKA2 | c.2407G>A p.V803I | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.867); catalogued as rs766866500, COSV101177617; called by muse, mutect2, varscan2
- PHRF1 | c.3089C>T p.S1030L (on ENST00000264555 / NM_001286581.2; = p.S1029L on NM_020901.4) | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.87); catalogued as rs763792441, COSV52758867; called by muse, mutect2, varscan2
- PHRF1 | c.4091C>T p.A1364V (on ENST00000264555 / NM_001286581.2; = p.A1363V on NM_020901.4) | Missense Mutation (SNP) | VAF 40/89 reads (45%) | SIFT tolerated (0.81); PolyPhen benign (0.003); catalogued as rs757261101, COSV99213785; called by muse, mutect2, varscan2
- PHYHIPL | c.766G>A p.A256T | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs369674396, COSV99514224; called by muse, mutect2, varscan2
- PISD | c.967del p.A323Pfs*33 (on ENST00000439502 / NM_001326412.1; = p.A289Pfs*33 on NM_014338.3) | Frame Shift Del (DEL) | VAF 22/77 reads (29%) | catalogued as COSV99837205; called by mutect2, pindel, varscan2
- PKD1 | c.2731G>A p.V911M | Missense Mutation (SNP) | VAF 110/272 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.483); catalogued as rs147447715; called by muse, mutect2, varscan2
- PLA2G4F | c.1885C>T p.R629C | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs765058508, COSV51829100; called by muse, mutect2
- PLEC | c.5988G>T p.K1996N (on ENST00000322810 / NM_201380.4; = p.K1886N on NM_000445.5) | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV100519847; called by muse, mutect2, varscan2
- PLEC | c.3286G>A p.G1096S (on ENST00000322810 / NM_201380.4; = p.G986S on NM_000445.5) | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs201071539; ClinVar: uncertain significance; called by muse, mutect2
- PLEKHB2 | c.173C>T p.T58M | Missense Mutation (SNP) | VAF 40/126 reads (32%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as rs771487921, COSV52177127; called by muse, mutect2, varscan2
- PLIN5 | c.806G>A p.R269H | Missense Mutation (SNP) | VAF 18/27 reads (67%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs770172740, COSV101113709; called by muse, mutect2, varscan2
- PLXNC1 | c.1819G>A p.A607T | Missense Mutation (SNP) | VAF 31/81 reads (38%) | SIFT tolerated (0.47); PolyPhen benign (0.003); catalogued as rs376243881; called by muse, mutect2, varscan2
- PLXND1 | c.3278G>A p.R1093H | Missense Mutation (SNP) | VAF 43/101 reads (43%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.938); catalogued as rs372693427; called by muse, mutect2, varscan2
- PNPLA4 | c.329G>A p.R110Q | Missense Mutation (SNP) | VAF 31/76 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as rs775251646, COSV101124444; called by muse, mutect2, varscan2
- POLR3C | c.619G>A p.E207K | Missense Mutation (SNP) | VAF 26/105 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.081); catalogued as COSV61936483; called by muse, mutect2, varscan2
- POMGNT2 | c.76C>T p.R26C | Missense Mutation (SNP) | VAF 31/46 reads (67%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as rs755067791, COSV100768175; called by muse, mutect2, varscan2
- POTEM | c.197G>A p.R66H | Missense Mutation (SNP) | VAF 56/459 reads (12%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); catalogued as rs768801095; called by muse, varscan2
- PPARGC1B | c.2320G>A p.A774T | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.14); catalogued as rs771936747, COSV100495272; called by muse, mutect2, varscan2
- PPL | c.4276C>T p.R1426W | Missense Mutation (SNP) | VAF 47/124 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.749); catalogued as rs989192412, COSV52174687; called by muse, mutect2, varscan2
- PPL | c.1362del p.T455Qfs*37 | Frame Shift Del (DEL) | VAF 24/65 reads (37%) | catalogued as rs753902804; called by mutect2, pindel, varscan2
- PPM1J | c.511C>T p.R171W | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.798); catalogued as rs140892250; called by muse, mutect2, varscan2
- PPP1R16B | c.1013G>A p.S338N | Missense Mutation (SNP) | VAF 44/190 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100240189; called by muse, mutect2, varscan2
- PPP1R26 | c.1058C>T p.A353V | Missense Mutation (SNP) | VAF 38/109 reads (35%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs149526868; called by muse, mutect2, varscan2
- PRKDC | c.7071G>T p.E2357D | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as COSV100043400; called by muse, mutect2, varscan2
- PRKDC | c.496del p.I166Yfs*6 | Frame Shift Del (DEL) | VAF 12/35 reads (34%) | catalogued as rs537061158; called by mutect2, varscan2
- PROSER1 | c.1567G>T p.A523S | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.57); catalogued as COSV100613111; called by muse, mutect2, varscan2
- PRPF31 | c.940G>T p.G314W | Missense Mutation (SNP) | VAF 25/49 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100320146; called by muse, mutect2, varscan2
- PRRC2B | c.1543C>T p.R515C | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs775941500, COSV61934862; called by muse, mutect2, varscan2
- PRRG1 | c.401dup p.P135Tfs*3 | Frame Shift Ins (INS) | VAF 26/70 reads (37%) | catalogued as rs781858060, COSV66158042; called by mutect2, varscan2
- PRRX1 | c.434G>A p.R145Q | Missense Mutation (SNP) | VAF 83/147 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1270473736, CM143963, COSV53413010; called by muse, mutect2, varscan2
- PRRX2 | c.418C>T p.R140C | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100991218; called by muse, mutect2, varscan2
- PSMA6 | c.439C>T p.Q147* | Nonsense Mutation (SNP) | VAF 13/38 reads (34%) | catalogued as COSV99809325; called by muse, mutect2, varscan2
- PTGDR2 | c.71G>A p.S24N | Missense Mutation (SNP) | VAF 17/90 reads (19%) | SIFT tolerated (0.38); PolyPhen benign (0.006); catalogued as rs757092179, COSV99920338; called by muse, mutect2, varscan2
- PTPN4 | c.2542G>A p.V848I | Missense Mutation (SNP) | VAF 56/131 reads (43%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as rs536503892, COSV55310446; called by muse, mutect2, varscan2
- PTPN6 | c.119C>T p.S40L | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as COSV100017331; called by muse, mutect2, varscan2
- PTPRU | c.523G>A p.G175S | Missense Mutation (SNP) | VAF 31/80 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.082); catalogued as COSV100113914; called by muse, mutect2, varscan2
- PUS1 | c.1252G>A p.E418K | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT tolerated (0.18); PolyPhen benign (0.005); catalogued as COSV100435310; called by muse, mutect2, varscan2
- PWWP2A | c.752T>C p.L251P | Missense Mutation (SNP) | VAF 14/90 reads (16%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV100194181; called by muse, mutect2, varscan2
- QRICH2 | c.3725C>T p.A1242V | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT tolerated (0.22); PolyPhen benign (0.006); catalogued as COSV53157079, COSV99429834; called by muse, mutect2, varscan2
- QTRT1 | c.1081C>T p.R361C | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs377094295, COSV51551527; called by muse, mutect2
- RAB11FIP4 | c.770C>T p.T257M | Missense Mutation (SNP) | VAF 51/96 reads (53%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.974); catalogued as COSV57929673; called by muse, mutect2, varscan2
- RAB11FIP5 | c.1276G>A p.A426T | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs144951768; called by muse, mutect2, varscan2
- RAB37 | c.148G>A p.G50S | Missense Mutation (SNP) | VAF 44/119 reads (37%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.798); catalogued as rs753157903, COSV61196708; called by muse, mutect2, varscan2
- RALGAPA1 | c.4322A>C p.Q1441P | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT tolerated (0.16); PolyPhen benign (0.014); catalogued as COSV99356430; called by muse, mutect2, varscan2
- RAP1GAP2 | c.1337C>T p.S446L | Missense Mutation (SNP) | VAF 33/65 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); catalogued as rs778744234, COSV99624613; called by muse, mutect2, varscan2
- RAP2B | c.356A>G p.D119G | Missense Mutation (SNP) | VAF 33/128 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100059183; called by muse, mutect2, varscan2
- RASL12 | c.307C>T p.R103C | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs776965372, COSV54982652, COSV99585249; called by muse, mutect2, varscan2
- RB1CC1 | c.71C>T p.T24I | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.796); catalogued as rs899072082, COSV99210648; called by mutect2, varscan2
- RBFOX1 | c.233C>T p.A78V | Missense Mutation (SNP) | VAF 35/90 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.029); catalogued as rs761205127, COSV60956442; called by muse, mutect2, varscan2
- RC3H1 | c.1833T>C p.G611= | Splice Region (SNP) | VAF 12/17 reads (71%) | catalogued as COSV99281885; called by muse, mutect2, varscan2
- REG1A | c.428G>A p.S143N | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as rs765761645, COSV52069446; called by muse, mutect2, varscan2
- RETREG2 | c.879+1G>A p.X293_splice | Splice Site (SNP) | VAF 21/38 reads (55%) | catalogued as COSV99811752; called by muse, mutect2, varscan2
- REXO1 | c.3373G>A p.V1125I | Missense Mutation (SNP) | VAF 26/44 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs1380954675, COSV99402708; called by muse, mutect2, varscan2
- RFX1 | c.2203C>T p.R735W | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.586); catalogued as rs758801717, COSV99586545; called by muse, mutect2, varscan2
- RHPN2 | c.1517C>T p.S506L | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.282); catalogued as rs777977646, COSV54278229; called by muse, mutect2, varscan2
- RLBP1 | c.175C>T p.R59W | Missense Mutation (SNP) | VAF 22/110 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99175414; called by muse, mutect2, varscan2
- RNF10 | c.304G>A p.G102S | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.031); catalogued as rs141915839; called by muse, mutect2, varscan2
- RNF14 | c.346G>C p.E116Q | Missense Mutation (SNP) | VAF 31/83 reads (37%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.649); catalogued as COSV100641323; called by muse, mutect2, varscan2
- RNF14 | c.496G>A p.E166K | Missense Mutation (SNP) | VAF 33/68 reads (49%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as COSV61662688; called by muse, mutect2, varscan2
- RNF14 | c.627G>C p.Q209H | Missense Mutation (SNP) | VAF 37/98 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.017); catalogued as COSV100641324; called by muse, mutect2, varscan2
- ROR2 | c.334C>T p.R112W | Missense Mutation (SNP) | VAF 21/109 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs868585233, COSV100996172; called by muse, mutect2, varscan2
- ROS1 | c.6200G>A p.C2067Y | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100877823; called by muse, mutect2, varscan2
- RPS9 | c.382G>A p.V128M | Missense Mutation (SNP) | VAF 34/93 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as rs754299712, COSV100256495; called by muse, mutect2, varscan2
- RPUSD4 | c.703C>T p.R235W | Missense Mutation (SNP) | VAF 26/52 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1565316712, COSV53599214; called by muse, mutect2, varscan2
- RS1 | c.101A>G p.Y34C | Missense Mutation (SNP) | VAF 38/87 reads (44%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.258); catalogued as COSV101183866; called by muse, mutect2, varscan2
- RSF1 | c.2183G>T p.R728M | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.887); catalogued as COSV100407806; called by muse, mutect2, varscan2
- RXFP3 | c.686C>T p.S229L | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.418); catalogued as COSV57506992; called by muse, mutect2, varscan2
- RYR1 | c.7697C>T p.A2566V | Missense Mutation (SNP) | VAF 37/87 reads (43%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.98); catalogued as rs1285547623, COSV62089550; called by muse, mutect2, varscan2
- RYR1 | c.9466G>A p.V3156I | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT deleterious (0.05); PolyPhen benign (0.095); catalogued as rs150230127; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RYR3 | c.3083G>A p.R1028H | Missense Mutation (SNP) | VAF 31/74 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.96); catalogued as rs575120914, COSV101212122, COSV66777575; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- S100A7 | c.166G>A p.A56T | Missense Mutation (SNP) | VAF 14/113 reads (12%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs762356824, COSV100906763; called by muse, mutect2, varscan2
- SAMD7 | c.796C>T p.H266Y | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.454); catalogued as COSV100157121; called by muse, mutect2, varscan2
- SBSPON | c.295C>T p.R99C | Missense Mutation (SNP) | VAF 32/69 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766329688, COSV52076876; called by muse, mutect2, varscan2
- SCARA3 | c.1378G>A p.G460S | Missense Mutation (SNP) | VAF 28/59 reads (47%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.913); catalogued as rs750778244, COSV100107101; called by muse, mutect2, varscan2
- SCLY | c.1201G>A p.G401R (on ENST00000651534; = p.G393R on NM_016510.7) | Missense Mutation (SNP) | VAF 28/159 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.929); catalogued as rs146021037; called by muse, mutect2, varscan2
- SCML1 | c.436C>T p.R146C (on ENST00000380041 / NM_001037540.3; = p.R119C on NM_006746.6) | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.725); catalogued as rs746477197, COSV66240760; called by muse, mutect2, varscan2
- SCN5A | c.5458G>A p.A1820T (on ENST00000333535 / NM_198056.3; = p.A1819T on NM_000335.5) | Missense Mutation (SNP) | VAF 39/51 reads (76%) | SIFT tolerated (0.56); PolyPhen benign (0.106); catalogued as rs764188413, COSV100351091; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SCN5A | c.2422C>T p.R808C | Missense Mutation (SNP) | VAF 33/44 reads (75%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); catalogued as rs749864465, CM1010021, COSV61143460; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SDR39U1 | c.770G>A p.R257H | Missense Mutation (SNP) | VAF 34/98 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs759354151, COSV52163973; called by muse, mutect2, varscan2
- SEC16A | c.5323G>A p.A1775T | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs778929428, COSV99259275; called by muse, varscan2
- SEMA6A | c.2737G>A p.G913R | Missense Mutation (SNP) | VAF 39/103 reads (38%) | SIFT tolerated (0.16); PolyPhen benign (0.178); catalogued as rs765850706, COSV56714683; called by muse, mutect2, varscan2
- SEMA6D | c.3104G>A p.G1035D (on ENST00000316364 / NM_153618.2; = p.G973D on NM_020858.2) | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.844); catalogued as rs1334371950, COSV100317757; called by muse, mutect2, varscan2
- SEPTIN4 | c.1267C>T p.R423W | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.937); catalogued as rs759153104, COSV100051530; called by muse, mutect2, varscan2
- SERPINH1 | c.533C>T p.A178V | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.771); catalogued as rs755143041, COSV63997825; called by muse, mutect2, varscan2
- SGSM3 | c.862G>A p.V288M | Missense Mutation (SNP) | VAF 33/73 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as rs376746554, COSV99960736; called by muse, mutect2, varscan2
- SH3RF1 | c.1726C>T p.H576Y | Missense Mutation (SNP) | VAF 41/100 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.172); catalogued as COSV99499616; called by muse, mutect2, varscan2
- SHANK1 | c.5849C>T p.P1950L | Missense Mutation (SNP) | VAF 58/113 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.011); catalogued as rs766455027, COSV99522221; called by muse, mutect2, varscan2
- SHANK1 | c.94G>A p.G32R | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.468); catalogued as rs756200161, COSV99522225; called by muse, mutect2, varscan2
- SHROOM3 | c.2284G>A p.G762S | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1384762055, COSV99935608; called by muse, mutect2, varscan2
- SIK3 | c.3932+1G>A p.X1311_splice (on ENST00000445177 / NM_001366686.2; = p.X1270_splice on NM_025164.6 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 12/50 reads (24%) | catalogued as COSV99408962; called by muse, varscan2
- SIVA1 | c.395G>A p.R132Q | Missense Mutation (SNP) | VAF 62/159 reads (39%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as rs753479469, COSV100328612; called by muse, mutect2, varscan2
- SKIV2L | c.2240C>T p.T747M | Missense Mutation (SNP) | VAF 27/68 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs752777790, COSV61714737; called by muse, mutect2, varscan2
- SLAMF7 | c.901A>G p.N301D | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.78); catalogued as COSV100833384; called by muse, mutect2, varscan2
- SLC16A1 | c.1499T>G p.V500G | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.637); catalogued as COSV100856119; called by muse, mutect2
- SLC17A9 | c.500C>T p.T167M | Missense Mutation (SNP) | VAF 64/128 reads (50%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.981); catalogued as rs768086850, COSV100948021; called by muse, mutect2, varscan2
- SLC1A6 | c.113G>A p.R38H | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.855); catalogued as COSV99694279; called by muse, mutect2
- SLC22A5 | c.559C>T p.Q187* | Nonsense Mutation (SNP) | VAF 97/256 reads (38%) | catalogued as COSV55374336; called by muse, mutect2, varscan2
- SLC23A2 | c.1063G>A p.V355M | Missense Mutation (SNP) | VAF 62/127 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as rs760070455, COSV57780162; called by muse, mutect2, varscan2
- SLC26A4 | c.1751C>T p.A584V | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs749479853, COSV55914647; called by muse, mutect2, varscan2
- SLC2A1 | c.488G>C p.G163A | Missense Mutation (SNP) | VAF 27/59 reads (46%) | SIFT tolerated (0.94); PolyPhen benign (0.006); catalogued as COSV100995988; called by muse, mutect2, varscan2
- SLC35A2 | c.173G>A p.R58H | Missense Mutation (SNP) | VAF 28/135 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1557043644, COSV99900625; called by muse, mutect2, varscan2
- SLC41A2 | c.644C>T p.A215V | Missense Mutation (SNP) | VAF 13/21 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV99317020; called by muse, mutect2, varscan2
- SLC6A17 | c.287-1G>T p.X96_splice | Splice Site (SNP) | VAF 58/168 reads (35%) | catalogued as COSV100521583; called by muse, mutect2, varscan2
- SLITRK5 | c.1004G>A p.R335H | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV61521791; called by muse, mutect2, varscan2
- SLK | c.2483G>A p.R828H | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100212209; called by muse, mutect2
- SMARCAD1 | c.1573-1G>T p.X525_splice | Splice Site (SNP) | VAF 24/35 reads (69%) | catalogued as COSV100759055; called by muse, mutect2, varscan2
- SMTN | c.323G>A p.R108H | Missense Mutation (SNP) | VAF 34/98 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1264430081, COSV100295009, COSV60780959; called by muse, mutect2, varscan2
- SMU1 | c.1450G>A p.E484K | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT tolerated (0.14); PolyPhen benign (0.152); catalogued as COSV101238601; called by muse, mutect2, varscan2
- SMURF2 | c.136C>T p.Q46* | Nonsense Mutation (SNP) | VAF 19/49 reads (39%) | catalogued as rs1555688260, COSV99301204; called by muse, mutect2, varscan2
- SNAPC4 | c.2815G>A p.G939S | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as rs371547779; called by muse, varscan2
- SNCAIP | c.1292G>A p.G431D | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs756859748, COSV99750679; called by muse, mutect2, varscan2
- SNX11 | c.416T>C p.V139A | Missense Mutation (SNP) | VAF 62/152 reads (41%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.984); catalogued as COSV100821813; called by muse, mutect2, varscan2
- SORBS1 | c.2009G>T p.G670V (on ENST00000361941 / NM_001034954.2; = p.G376V on NM_006434.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/23 reads (57%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.925); catalogued as COSV99529101; called by muse, mutect2, varscan2
- SOWAHB | c.1574G>A p.R525H | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs370031316; called by muse, mutect2, varscan2
- SOX12 | c.684G>T p.E228D | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT tolerated (0.21); PolyPhen benign (0.191); catalogued as COSV100705305; called by muse, mutect2, varscan2
- SPAG17 | c.4896G>T p.Q1632H | Missense Mutation (SNP) | VAF 20/34 reads (59%) | SIFT tolerated (0.24); PolyPhen benign (0.35); catalogued as rs1250853233, COSV100310907; called by muse, mutect2, varscan2
- SPEG | c.8207C>T p.T2736I | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.036); catalogued as COSV100405876; called by muse, mutect2, varscan2
- SPEN | c.3508C>T p.R1170* | Nonsense Mutation (SNP) | VAF 3/13 reads (23%) | catalogued as COSV65366474; called by muse, mutect2
- SPNS1 | c.1207G>A p.A403T | Missense Mutation (SNP) | VAF 44/138 reads (32%) | SIFT tolerated (0.18); PolyPhen benign (0.241); catalogued as rs947470890, COSV100209359; called by muse, mutect2, varscan2
- SPRING1 | c.448C>T p.R150W | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as rs201890321, COSV54338606; called by muse, mutect2, varscan2
- SPRTN | c.446T>A p.I149K | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99150172; called by muse, mutect2, varscan2
- SPTBN5 | c.5792G>A p.R1931H | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT tolerated (0.46); PolyPhen benign (0.03); catalogued as rs757182673, COSV58023484; called by muse, mutect2, varscan2
- SRGAP1 | c.50A>G p.Y17C | Missense Mutation (SNP) | VAF 80/184 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.006); catalogued as COSV100755207; called by muse, mutect2, varscan2
- SRRM4 | c.1439G>A p.R480H | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.007); catalogued as COSV57421278; called by muse, mutect2, varscan2
- SS18L1 | c.298C>T p.H100Y | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100065479; called by muse, mutect2, varscan2
- STAT5A | c.911C>T p.P304L | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.096); catalogued as COSV100604867; called by muse, mutect2, varscan2
- STOML2 | c.215G>A p.R72Q | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT tolerated (0.09); PolyPhen benign (0.094); catalogued as rs763483882, COSV59716263; called by muse, mutect2, varscan2
- STRAP | c.724G>A p.G242S | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.397); catalogued as rs185224819, COSV50308607; called by muse, mutect2, varscan2
- STRN | c.1486G>A p.A496T | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.01); catalogued as COSV99815793; called by muse, mutect2, varscan2
- STUM | c.233G>A p.C78Y | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100828348; called by muse, mutect2, varscan2
- STXBP3 | c.1633C>T p.R545C | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs750050452, COSV64181653; called by muse, mutect2, varscan2
- STYXL1 | c.932C>T p.P311L | Missense Mutation (SNP) | VAF 30/60 reads (50%) | SIFT tolerated (0.13); PolyPhen benign (0.204); catalogued as rs1163715541, COSV50389175; called by muse, mutect2, varscan2
- SUGP1 | c.271C>T p.Q91* | Nonsense Mutation (SNP) | VAF 8/50 reads (16%) | catalogued as COSV99895674; called by muse, mutect2, varscan2
- SVOPL | c.1277C>T p.T426M (on ENST00000419765; = p.T274M on NM_174959.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs765749268, COSV55992580; called by muse, mutect2, varscan2
- SYMPK | c.3032G>A p.R1011H | Missense Mutation (SNP) | VAF 46/110 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.688); catalogued as rs749914244, COSV99680176; called by muse, mutect2, varscan2
- SYNE1 | c.14882C>T p.A4961V (on ENST00000367255 / NM_182961.4; = p.A4890V on NM_033071.3) | Missense Mutation (SNP) | VAF 33/72 reads (46%) | SIFT tolerated (0.18); PolyPhen benign (0.012); catalogued as rs774556402, COSV54900854; called by muse, mutect2, varscan2
- SYNRG | c.3646A>G p.M1216V | Missense Mutation (SNP) | VAF 32/87 reads (37%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.959); catalogued as rs1426380722; called by muse, mutect2
- SZT2 | c.6361C>T p.R2121* (on ENST00000634258 / NM_001365999.1; = p.R2064* on NM_015284.4) | Nonsense Mutation (SNP) | VAF 31/72 reads (43%) | catalogued as rs550692594, COSV100987713; called by muse, mutect2, varscan2
- TACC2 | c.3421C>T p.P1141S | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as COSV100554285; called by muse, mutect2, varscan2
- TACC2 | c.4922T>C p.L1641S | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0); catalogued as rs202019397, COSV100554287; called by muse, mutect2, varscan2
- TAF1C | c.554C>T p.S185L | Missense Mutation (SNP) | VAF 27/56 reads (48%) | SIFT tolerated (0.62); PolyPhen possibly damaging (0.56); catalogued as rs200602141, COSV100499826; called by muse, mutect2, varscan2
- TARBP2 | c.805C>T p.R269* (on ENST00000266987 / NM_134323.2; = p.R248* on NM_004178.4) | Nonsense Mutation (SNP) | VAF 54/119 reads (45%) | catalogued as rs769325580, COSV99908664; called by muse, mutect2, varscan2
- TCAF1 | c.2299G>A p.E767K | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.028); catalogued as COSV100584569, COSV100584660; called by mutect2, varscan2
- TCOF1 | c.1978C>T p.R660* (on ENST00000377797 / NM_001135243.1; = p.R583* on NM_000356.4) | Nonsense Mutation (SNP) | VAF 13/31 reads (42%) | catalogued as CM051654, COSV100077327; called by muse, mutect2, varscan2
- TECPR1 | c.275G>A p.R92H | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs900630878, COSV101130817; called by muse, mutect2, varscan2
- TGFB3 | c.463C>T p.R155W | Missense Mutation (SNP) | VAF 27/65 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs868258653, COSV53171156; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- THAP10 | c.124G>A p.A42T | Missense Mutation (SNP) | VAF 36/88 reads (41%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as COSV99538336; called by muse, mutect2, varscan2
- TIA1 | c.398+1G>A p.X133_splice (on ENST00000433529 / NM_001351511.1; = p.X122_splice on NM_022037.4 and 9 other RefSeq transcripts) | Splice Site (SNP) | VAF 11/23 reads (48%) | catalogued as COSV57007720; called by muse, mutect2, varscan2
- TLL2 | c.2749G>A p.A917T | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.492); catalogued as rs1185088674, COSV100780293; called by muse, mutect2, varscan2
- TMEM120B | c.208C>T p.R70W | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs767611154, COSV100699727; called by muse, mutect2, varscan2
- TMEM131 | c.5176G>A p.A1726T | Missense Mutation (SNP) | VAF 29/70 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.267); catalogued as rs1041074642, COSV99489892; called by muse, mutect2, varscan2
- TMEM132E | c.29G>C p.G10A | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.001); catalogued as rs946545688, COSV58697229; called by mutect2, varscan2
- TMEM184C | c.836C>T p.T279M | Missense Mutation (SNP) | VAF 23/38 reads (61%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.636); catalogued as rs745856724, COSV99669492; called by muse, mutect2, varscan2
- TMEM79 | c.1021G>A p.G341S | Missense Mutation (SNP) | VAF 76/130 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1380465325, COSV99828181; called by muse, mutect2, varscan2
- TNKS2 | c.1366G>T p.G456W | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65416613; called by muse, mutect2, varscan2
- TNS3 | c.4322C>T p.S1441F | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV60796940; called by muse, mutect2, varscan2
- TOGARAM2 | c.565G>A p.G189R | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT tolerated (0.13); PolyPhen benign (0.01); catalogued as rs762302618, COSV101091556; called by muse, mutect2, varscan2
- TOMM70 | c.1340G>A p.R447H | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99424657; called by muse, mutect2
- TPRX1 | c.737C>T p.P246L | Missense Mutation (SNP) | VAF 95/256 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs760916247, COSV100445957; called by muse, mutect2, varscan2
- TPST2 | c.485C>T p.T162M | Missense Mutation (SNP) | VAF 34/94 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs770653345, COSV58679694; called by muse, mutect2, varscan2
- TRAPPC1 | c.379C>T p.R127C | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.74); catalogued as rs148790381; called by muse, mutect2, varscan2
- TRIL | c.2311G>A p.V771M | Missense Mutation (SNP) | VAF 50/136 reads (37%) | SIFT tolerated (0.24); PolyPhen benign (0.191); catalogued as COSV100539008; called by muse, mutect2, varscan2
- TRIM2 | c.652C>T p.R218C (on ENST00000437508; = p.R245C on NM_015271.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/25 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs754843842, COSV58631517; called by muse, mutect2, varscan2
- TRIM28 | c.989G>A p.R330Q | Missense Mutation (SNP) | VAF 39/103 reads (38%) | SIFT tolerated (0.88); PolyPhen possibly damaging (0.47); catalogued as COSV99449529; called by muse, mutect2, varscan2
- TRIM6 | c.28C>T p.R10* | Nonsense Mutation (SNP) | VAF 11/65 reads (17%) | catalogued as rs572665146, COSV99546935; called by muse, mutect2, varscan2
- TRMT2A | c.706C>T p.Q236* | Nonsense Mutation (SNP) | VAF 20/57 reads (35%) | catalogued as rs746180847, COSV99350360; called by muse, varscan2
- TRPM2 | c.1115C>T p.S372L | Missense Mutation (SNP) | VAF 37/94 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.359); catalogued as rs764271519, COSV100309438; called by muse, mutect2, varscan2
- TRPM4 | c.883C>G p.Q295E | Missense Mutation (SNP) | VAF 27/69 reads (39%) | SIFT tolerated (0.16); PolyPhen benign (0.068); catalogued as COSV99421096; called by muse, mutect2, varscan2
- TSC1 | c.2303G>A p.R768H | Missense Mutation (SNP) | VAF 56/103 reads (54%) | SIFT tolerated (0.27); PolyPhen benign (0.007); catalogued as rs1033725987, COSV53772119; ClinVar: uncertain significance / benign; called by muse, mutect2, varscan2
- TSPAN10 | c.610G>A p.V204M (on ENST00000574882 / NM_001290212.1; = p.V166M on NM_031945.4) | Missense Mutation (SNP) | VAF 49/116 reads (42%) | SIFT tolerated (0.11); PolyPhen benign (0.134); catalogued as rs374329590; called by muse, mutect2, varscan2
- TSPOAP1 | c.5141T>G p.L1714R | Missense Mutation (SNP) | VAF 44/95 reads (46%) | SIFT tolerated (0.18); PolyPhen benign (0.277); catalogued as COSV99273182; called by muse, mutect2, varscan2
- TSR3 | c.397C>T p.P133S | Missense Mutation (SNP) | VAF 27/90 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs754994733, COSV99136418; called by muse, mutect2, varscan2
- TTC30A | c.1343G>A p.R448H | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.021); catalogued as rs772291794, COSV100826247; called by muse, mutect2
- TTLL5 | c.1028G>A p.R343H | Missense Mutation (SNP) | VAF 25/126 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); catalogued as rs759880353, COSV54042875; called by muse, mutect2, varscan2
- TTN | c.89348C>T p.A29783V (on ENST00000591111; = p.A22359V on NM_003319.4) | Missense Mutation (SNP) | VAF 26/58 reads (45%) | PolyPhen benign (0.012); catalogued as rs1178719189, COSV100634234; called by muse, mutect2, varscan2
- TUBB8 | c.120C>G p.S40R | Missense Mutation (SNP) | VAF 38/82 reads (46%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.952); catalogued as COSV100226223; called by muse, mutect2, varscan2
- TULP4 | c.1207del p.R403Afs*24 | Frame Shift Del (DEL) | VAF 29/77 reads (38%) | catalogued as rs746002490; called by mutect2, pindel, varscan2
- TVP23C | c.229T>C p.W77R | Missense Mutation (SNP) | VAF 36/88 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779026862, COSV99847106; called by muse, varscan2
- TXLNB | c.787C>T p.Q263* | Nonsense Mutation (SNP) | VAF 23/106 reads (22%) | catalogued as COSV100625212, COSV62727377; called by muse, mutect2, varscan2
- TYK2 | c.1501C>T p.R501W | Missense Mutation (SNP) | VAF 33/71 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.462); catalogued as rs756944840, COSV53386488; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- UBE2E3 | c.41G>A p.S14N | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.001); catalogued as COSV101150666; called by muse, mutect2, varscan2
- UBE2M | c.521G>A p.G174D | Missense Mutation (SNP) | VAF 27/73 reads (37%) | SIFT tolerated (0.3); PolyPhen benign (0.031); catalogued as COSV99448418; called by muse, mutect2, varscan2
- UBR4 | c.10237C>T p.R3413C | Missense Mutation (SNP) | VAF 25/50 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.23); catalogued as COSV64386076; called by muse, mutect2, varscan2
- UNC13A | c.1049A>T p.E350V | Missense Mutation (SNP) | VAF 28/79 reads (35%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.022); catalogued as COSV99409818; called by muse, mutect2, varscan2
- UNC5B | c.541C>T p.P181S | Missense Mutation (SNP) | VAF 28/114 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.23); catalogued as rs1185515736, COSV100101459; called by muse, mutect2, varscan2
- UPK3A | c.691G>A p.A231T | Missense Mutation (SNP) | VAF 19/89 reads (21%) | SIFT tolerated (0.26); PolyPhen benign (0.036); catalogued as rs758703602, COSV99343244; called by muse, mutect2, varscan2
- UROC1 | c.1729G>A p.V577M | Missense Mutation (SNP) | VAF 14/114 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs773916999, COSV52032025; called by mutect2, varscan2
- USHBP1 | c.410G>A p.R137H | Missense Mutation (SNP) | VAF 24/140 reads (17%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.997); catalogued as rs199702527, COSV53105679; called by muse, mutect2, varscan2
- USP21 | c.565C>T p.R189W | Missense Mutation (SNP) | VAF 36/126 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs760197993, COSV99237573, COSV99237886; called by muse, mutect2, varscan2
- USP26 | c.1836dup p.G613Rfs*6 | Frame Shift Ins (INS) | VAF 12/26 reads (46%) | catalogued as rs749830910; called by mutect2, varscan2
- USP28 | c.421C>T p.R141C | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs745453193, COSV50156931; called by muse, mutect2, varscan2
- USP32 | c.2573G>A p.R858Q | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs768392859, COSV100343044; called by muse, mutect2, varscan2
- USP42 | c.3695G>A p.R1232K | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated (0.23); PolyPhen benign (0.047); catalogued as rs1020193863, COSV100084386, COSV100084996; called by muse, mutect2, varscan2
- USP47 | c.1502G>C p.G501A (on ENST00000399455 / NM_001372095.1; = p.G413A on NM_017944.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 21/84 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100360047; called by muse, mutect2, varscan2
- UTS2R | c.215C>T p.T72M | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100493415; called by muse, mutect2, varscan2
- VDAC2 | c.266A>C p.D89A | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.065); catalogued as COSV100041161; called by muse, mutect2, varscan2
- VIPR2 | c.211G>A p.V71I | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.876); catalogued as rs772803993, COSV51103447; called by muse, mutect2, varscan2
- VPS52 | c.2060G>A p.R687H | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as rs975538675, COSV101408764; called by muse, mutect2, varscan2
- VSIG10 | c.737G>A p.R246H | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.012); catalogued as rs774654305, COSV63654016; called by mutect2, varscan2
- WIPI1 | c.922C>T p.R308C | Missense Mutation (SNP) | VAF 49/122 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.886); catalogued as rs554506311, COSV100048664; called by muse, mutect2, varscan2
- WNK1 | c.1268C>T p.S423L | Missense Mutation (SNP) | VAF 34/82 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV60025039; called by muse, mutect2, varscan2
- WWC2 | c.2512G>C p.E838Q | Missense Mutation (SNP) | VAF 20/39 reads (51%) | SIFT tolerated (0.19); PolyPhen benign (0.203); catalogued as COSV100968657; called by muse, mutect2, varscan2
- WWP1 | c.257G>A p.R86H | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs371650373; called by muse, mutect2, varscan2
- YBX1 | c.611G>A p.R204H | Missense Mutation (SNP) | VAF 28/78 reads (36%) | SIFT tolerated (0.26); PolyPhen benign (0.011); catalogued as rs780773403, COSV100172255; called by muse, mutect2, varscan2
- YTHDC2 | c.945+1G>A p.X315_splice | Splice Site (SNP) | VAF 16/58 reads (28%) | catalogued as COSV99363985; called by muse, mutect2, varscan2
- YY2 | c.190C>T p.P64S | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV100810867; called by muse, mutect2, varscan2
- Z83844.2 | c.1180G>A p.V394I | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT tolerated (0.59); PolyPhen benign (0.106); catalogued as rs754015130, COSV100379321, COSV100379412; called by muse, mutect2, varscan2
- ZBED9 | c.896G>A p.R299Q | Missense Mutation (SNP) | VAF 36/97 reads (37%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.14); catalogued as rs1055423005, COSV101509416; called by muse, mutect2, varscan2
- ZBTB46 | c.1394C>T p.T465M | Missense Mutation (SNP) | VAF 61/140 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as COSV55507522; called by muse, mutect2, varscan2
- ZC3H12D | c.542G>A p.R181H | Missense Mutation (SNP) | VAF 39/85 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1343491727, COSV66324590; called by muse, mutect2, varscan2
- ZC3HAV1 | c.1409G>A p.R470Q | Missense Mutation (SNP) | VAF 23/49 reads (47%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as rs779627291, COSV54302996; called by muse, mutect2, varscan2
- ZCWPW2 | c.797C>T p.T266M | Missense Mutation (SNP) | VAF 22/31 reads (71%) | SIFT deleterious (0); PolyPhen possibly damaging (0.765); catalogued as rs761086627, COSV101075410; called by muse, mutect2, varscan2
- ZFP57 | c.452G>A p.C151Y | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.018); catalogued as COSV100971991; called by muse, mutect2, varscan2
- ZFP82 | c.590C>T p.P197L | Missense Mutation (SNP) | VAF 27/56 reads (48%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as rs200935785, COSV101089381; called by muse, mutect2, varscan2
- ZFPL1 | c.245G>A p.R82H | Missense Mutation (SNP) | VAF 33/85 reads (39%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as rs751924582, COSV99298079; called by muse, mutect2, varscan2
- ZFYVE28 | c.170G>A p.R57H | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.997); catalogued as COSV52109542; called by muse, mutect2, varscan2
- ZMYM3 | c.1397G>T p.G466V | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.028); catalogued as COSV100078484; called by muse, mutect2, varscan2
- ZNF219 | c.715G>A p.E239K | Missense Mutation (SNP) | VAF 11/18 reads (61%) | SIFT tolerated, low confidence (0.94); PolyPhen benign (0.074); catalogued as rs1194697276, COSV100070758; called by muse, mutect2, varscan2
- ZNF250 | c.1162G>A p.V388M | Missense Mutation (SNP) | VAF 40/80 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs765142365, COSV52969440; called by muse, mutect2, varscan2
- ZNF263 | c.1907G>A p.C636Y | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99527195; called by muse, mutect2, varscan2
- ZNF319 | c.1315C>T p.R439C | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.947); catalogued as rs563911549, COSV54623342; called by muse, mutect2, varscan2
- ZNF335 | c.758G>A p.R253Q | Missense Mutation (SNP) | VAF 47/131 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.593); catalogued as rs765861359, COSV59817799; called by muse, mutect2, varscan2
- ZNF347 | c.1414C>T p.L472F | Missense Mutation (SNP) | VAF 6/94 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.784); catalogued as COSV100498400; called by muse, mutect2
- ZNF365 | c.1196del p.K399Sfs*6 | Frame Shift Del (DEL) | VAF 6/28 reads (21%) | catalogued as rs751774089; called by mutect2, varscan2
- ZNF471 | c.917C>T p.A306V | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT tolerated (0.6); PolyPhen benign (0.227); catalogued as COSV100340929; called by muse, mutect2, varscan2
- ZNF474 | c.652C>T p.R218* | Nonsense Mutation (SNP) | VAF 17/42 reads (40%) | catalogued as rs774506819, COSV99682350; called by muse, mutect2, varscan2
- ZNF552 | c.58G>T p.A20S | Missense Mutation (SNP) | VAF 48/131 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV101197572; called by muse, mutect2, varscan2
- ZNF676 | c.562C>A p.L188I (on ENST00000650058; = p.L156I on NM_001001411.3) | Missense Mutation (SNP) | VAF 35/84 reads (42%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.792); catalogued as COSV68093536; called by muse, mutect2, varscan2
- ZNF680 | c.920C>T p.A307V | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.058); catalogued as COSV100549366; called by muse, mutect2, varscan2
- ZNF70 | c.703C>T p.R235W | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT tolerated (0.18); PolyPhen benign (0.01); catalogued as rs556949511, COSV59532147; called by muse, mutect2, varscan2
- ZNF74 | c.601C>T p.R201C | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs572546166, COSV62621410; called by muse, mutect2, varscan2
- ZNF746 | c.1568C>T p.A523V | Missense Mutation (SNP) | VAF 28/60 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.74); catalogued as COSV61406896; called by muse, mutect2, varscan2
- ZNF777 | c.1102G>A p.V368M | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as rs375364322; called by muse, mutect2, varscan2
- ZNF778 | c.1637C>T p.S546L | Missense Mutation (SNP) | VAF 29/64 reads (45%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs375806694; called by muse, mutect2, varscan2
- ZNF780B | c.1153G>T p.G385C | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99666263; called by muse, mutect2, varscan2
- ZNF821 | c.439G>A p.A147T (on ENST00000425432 / NM_001376297.1; = p.A105T on NM_017530.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT tolerated (0.29); PolyPhen benign (0.041); catalogued as rs377750355; called by muse, mutect2, varscan2
- ZNF827 | c.2500C>T p.R834* | Nonsense Mutation (SNP) | VAF 24/35 reads (69%) | catalogued as COSV65226778; called by muse, mutect2, varscan2
- ZNF91 | c.815G>A p.G272D | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.487); catalogued as COSV100323580; called by muse, mutect2, varscan2
- ZSWIM4 | c.1102C>T p.L368F | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.624); catalogued as COSV99585522; called by muse, mutect2, varscan2
- ACACA | c.3616C>T p.R1206C | Missense Mutation (SNP) | VAF 27/75 reads (36%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- ADGRV1 | c.1772_1773del p.Q591Rfs*10 | Frame Shift Del (DEL) | VAF 22/51 reads (43%) | called by mutect2, pindel, varscan2
- AGTPBP1 | c.2882C>T p.P961L (on ENST00000357081 / NM_001330701.2; = p.P921L on NM_015239.2) | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- ANKHD1-EIF4EBP3 | c.4215del p.K1405Nfs*10 | Frame Shift Del (DEL) | VAF 21/46 reads (46%) | called by mutect2, pindel, varscan2
- AP5B1 | c.1462C>T p.H488Y | Missense Mutation (SNP) | VAF 3/45 reads (7%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.447); called by muse, mutect2
- COL15A1 | c.3659dup p.L1220Ffs*15 | Frame Shift Ins (INS) | VAF 19/56 reads (34%) | called by mutect2, pindel, varscan2
- EPHA2 | c.1379del p.P460Rfs*33 | Frame Shift Del (DEL) | VAF 34/89 reads (38%) | called by mutect2, pindel, varscan2
- KIAA1549 | c.2316del p.G773Afs*8 | Frame Shift Del (DEL) | VAF 8/27 reads (30%) | called by mutect2, pindel, varscan2
- LIG4 | c.1880del p.K627Sfs*8 | Frame Shift Del (DEL) | VAF 7/51 reads (14%) | called by mutect2, pindel, varscan2
- LRRK2 | c.7463_7475del p.X2488_splice | Splice Site (DEL) | VAF 9/40 reads (23%) | called by pindel, varscan2
- MIGA1 | c.1322dup p.L441Ffs*9 | Frame Shift Ins (INS) | VAF 17/44 reads (39%) | called by mutect2, pindel, varscan2
- MMP12 | c.193C>A p.Q65K | Missense Mutation (SNP) | VAF 3/43 reads (7%) | SIFT tolerated (0.69); PolyPhen benign (0.018); called by muse, mutect2
- NARS2 | c.124dup p.E42Gfs*4 | Frame Shift Ins (INS) | VAF 33/91 reads (36%) | called by mutect2, pindel, varscan2
- PNMA3 | c.301dup p.E101Gfs*81 | Frame Shift Ins (INS) | VAF 18/52 reads (35%) | called by mutect2, pindel, varscan2
- SAMD9L | c.63del p.K21Nfs*3 | Frame Shift Del (DEL) | VAF 20/55 reads (36%) | called by mutect2, pindel, varscan2
- TFE3 | c.1478del p.P493Lfs*33 | Frame Shift Del (DEL) | VAF 46/143 reads (32%) | called by mutect2, pindel, varscan2
- TMTC1 | c.1272dup p.V425Cfs*39 (on ENST00000539277 / NM_001193451.2; = p.V317Cfs*39 on NM_175861.3) | Frame Shift Ins (INS) | VAF 10/36 reads (28%) | called by mutect2, pindel
- TTBK1 | c.785dup p.H263Afs*32 | Frame Shift Ins (INS) | VAF 22/62 reads (35%) | called by mutect2, pindel, varscan2
- UBXN10 | c.829dup p.E277Gfs*12 | Frame Shift Ins (INS) | VAF 25/67 reads (37%) | called by mutect2, pindel, varscan2
- USH2A | c.3655dup p.S1219Ffs*7 | Frame Shift Ins (INS) | VAF 9/48 reads (19%) | called by mutect2, pindel, varscan2
- ZBTB20 | c.2075del p.P692Lfs*43 (on ENST00000474710 / NM_001164342.2; = p.P619Lfs*43 on NM_015642.6 and 4 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 22/116 reads (19%) | called by mutect2, pindel, varscan2
- ZNF44 | c.766del p.W256Gfs*34 (on ENST00000356109 / NM_001164276.2; = p.W208Gfs*34 on NM_016264.4 and 5 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 27/93 reads (29%) | called by mutect2, pindel, varscan2
- A2M | c.246C>T p.D82= | Silent (SNP) | VAF 26/68 reads (38%) | catalogued as rs752368777, COSV59382553; called by muse, mutect2, varscan2
- ABCC6 | c.2886C>T p.F962= | Silent (SNP) | VAF 23/60 reads (38%) | catalogued as rs765924261, COSV99229826; called by muse, mutect2, varscan2
- ACP6 | c.291T>G p.A97= | Silent (SNP) | VAF 10/70 reads (14%) | catalogued as COSV100984267; called by mutect2, varscan2
- AKAP1 | c.2181G>A p.Q727= | Silent (SNP) | VAF 22/53 reads (42%) | catalogued as COSV100533215; called by muse, mutect2, varscan2
- AMBP | c.567C>T p.V189= | Silent (SNP) | VAF 17/52 reads (33%) | catalogued as COSV99469442; called by muse, mutect2, varscan2
- ANKRD2 | c.522C>T p.A174= | Silent (SNP) | VAF 27/50 reads (54%) | catalogued as rs140424419; called by muse, mutect2, varscan2
- AP5B1 | c.711C>A p.P237= | Silent (SNP) | VAF 46/110 reads (42%) | catalogued as COSV100376189; called by muse, mutect2, varscan2
- APOM | c.99C>T p.G33= | Silent (SNP) | VAF 39/62 reads (63%) | catalogued as rs535853455, COSV52997076; called by muse, mutect2, varscan2
- ATG9B | c.2244C>T p.R748= | Silent (SNP) | VAF 9/47 reads (19%) | catalogued as rs369342990; called by muse, mutect2, varscan2
- ATG9B | c.1818C>T p.P606= | Silent (SNP) | VAF 14/43 reads (33%) | catalogued as rs769023129, COSV99872311; called by muse, mutect2, varscan2
- AXIN1 | c.1539C>T p.H513= | Silent (SNP) | VAF 86/224 reads (38%) | catalogued as rs1005870799, COSV99250424; called by muse, mutect2
- BAHCC1 | c.2244G>A p.A748= | Silent (SNP) | VAF 74/179 reads (41%) | catalogued as rs1555653484, COSV100311257; called by muse, mutect2, varscan2
- BCR | c.2277C>T p.L759= | Silent (SNP) | VAF 16/51 reads (31%) | catalogued as COSV100005819; called by muse, mutect2, varscan2
- BDNF | c.417C>T p.S139= | Silent (SNP) | VAF 20/79 reads (25%) | catalogued as rs760274076, COSV100151996; ClinVar: likely benign; called by muse, mutect2, varscan2
- BRWD3 | c.346C>T p.L116= | Silent (SNP) | VAF 13/46 reads (28%) | catalogued as COSV100956637; called by muse, mutect2, varscan2
- CACNA1C | c.1665C>T p.V555= | Silent (SNP) | VAF 9/100 reads (9%) | catalogued as COSV100223153; called by muse, mutect2
- CD244 | c.813C>T p.Y271= (on ENST00000368033 / NM_001166663.2; = p.Y266= on NM_016382.4) | Silent (SNP) | VAF 16/77 reads (21%) | catalogued as rs200584018, COSV100458820, COSV100458923; called by muse, mutect2, varscan2
- CDC14A | c.1710C>A p.T570= | Silent (SNP) | VAF 15/23 reads (65%) | catalogued as COSV100326125; called by muse, mutect2, varscan2
- CDK5 | c.141C>T p.S47= | Silent (SNP) | VAF 6/35 reads (17%) | catalogued as rs760579593, COSV99877496; called by muse, mutect2, varscan2
- CDS2 | c.123C>T p.S41= | Silent (SNP) | VAF 36/58 reads (62%) | catalogued as rs372748731; called by muse, mutect2, varscan2
- CLCC1 | c.1350A>G p.A450= (on ENST00000356970 / NM_001377464.1; = p.A400= on NM_015127.5) | Silent (SNP) | VAF 26/64 reads (41%) | catalogued as COSV100206745; called by muse, mutect2, varscan2
- CLEC18A | c.432C>T p.N144= | Silent (SNP) | VAF 41/86 reads (48%) | catalogued as rs760360182, COSV99846961; called by muse, mutect2, varscan2
- CMTM3 | c.531C>T p.S177= | Silent (SNP) | VAF 32/96 reads (33%) | catalogued as rs776349331, COSV100411955; called by muse, mutect2, varscan2
- COG7 | c.1368C>A p.S456= | Silent (SNP) | VAF 20/64 reads (31%) | catalogued as COSV100207806, COSV100207888; called by muse, mutect2, varscan2
- CPEB1 | c.1647C>T p.S549= (on ENST00000617958; = p.S484= on NM_030594.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 20/51 reads (39%) | catalogued as rs374011661, COSV99917574; called by muse, mutect2, varscan2
- CRELD2 | c.876C>T p.D292= | Silent (SNP) | VAF 12/51 reads (24%) | catalogued as rs145071099, COSV100078355; called by muse, mutect2, varscan2
- CUBN | c.10029G>A p.P3343= | Silent (SNP) | VAF 24/53 reads (45%) | catalogued as rs370204059, COSV64721982; called by muse, mutect2, varscan2
- CYP27C1 | c.498G>A p.T166= | Silent (SNP) | VAF 35/74 reads (47%) | catalogued as rs547358849, COSV58868153; called by muse, mutect2, varscan2
- DAD1 | c.9G>A p.A3= | Silent (SNP) | VAF 8/18 reads (44%) | catalogued as rs778894951, COSV99164732; called by muse, mutect2, varscan2
- DEF6 | c.180C>T p.D60= | Silent (SNP) | VAF 40/92 reads (43%) | catalogued as rs776898412, COSV57355140; called by muse, mutect2, varscan2
- DENND2A | c.1638G>A p.A546= | Silent (SNP) | VAF 6/24 reads (25%) | catalogued as rs376779332; called by muse, mutect2, varscan2
- DNAH1 | c.9075C>A p.T3025= | Silent (SNP) | VAF 19/59 reads (32%) | catalogued as COSV101327288; called by muse, mutect2, varscan2
- DNMBP | c.1791C>T p.T597= | Silent (SNP) | VAF 26/57 reads (46%) | catalogued as rs752389732, COSV100143894, COSV100144525; called by muse, mutect2, varscan2
- DOCK11 | c.2973C>T p.P991= | Silent (SNP) | VAF 14/41 reads (34%) | catalogued as rs758640363, COSV52236007; called by muse, mutect2, varscan2
- DOLPP1 | c.693C>T p.R231= | Silent (SNP) | VAF 10/20 reads (50%) | catalogued as rs1444894089, COSV100588480; called by muse, mutect2, varscan2
- E4F1 | c.1875G>A p.P625= | Silent (SNP) | VAF 22/50 reads (44%) | catalogued as rs762289883, COSV57040722; called by muse, mutect2, varscan2
- EBF1 | c.792C>A p.I264= | Silent (SNP) | VAF 11/31 reads (35%) | catalogued as COSV100566764, COSV58175641; called by muse, mutect2, varscan2
- ELAVL3 | c.573G>A p.P191= | Silent (SNP) | VAF 42/99 reads (42%) | catalogued as rs369340807; called by muse, mutect2, varscan2
- ESCO2 | c.315T>C p.S105= | Silent (SNP) | VAF 12/27 reads (44%) | catalogued as COSV100533452; called by muse, mutect2, varscan2
- FAM47B | c.1290C>T p.T430= | Silent (SNP) | VAF 37/82 reads (45%) | catalogued as rs1350753109, COSV100264784, COSV61456172; called by muse, mutect2, varscan2
- FAM47B | c.1608G>A p.P536= | Silent (SNP) | VAF 16/59 reads (27%) | catalogued as rs1423757807, COSV100264207; called by muse, mutect2, varscan2
- FARP1 | c.2967C>T p.S989= | Silent (SNP) | VAF 9/83 reads (11%) | catalogued as rs534082071, COSV100132307; called by muse, mutect2, varscan2
- FARP2 | c.2754C>T p.S918= | Silent (SNP) | VAF 16/46 reads (35%) | catalogued as rs373471419, COSV99885725; called by muse, mutect2, varscan2
- FBXO40 | c.204C>T p.S68= | Silent (SNP) | VAF 47/72 reads (65%) | catalogued as rs201758749; called by muse, mutect2, varscan2
- FLNC | c.612C>T p.P204= | Silent (SNP) | VAF 31/75 reads (41%) | catalogued as rs368103032; ClinVar: likely benign; called by muse, mutect2, varscan2
- FPGS | c.873G>A p.P291= | Silent (SNP) | VAF 6/43 reads (14%) | catalogued as rs769926008, COSV100948805, COSV64675741; called by muse, mutect2, varscan2
- FRMD3 | c.342T>C p.H114= | Silent (SNP) | VAF 9/20 reads (45%) | catalogued as rs756814626, COSV100419256; called by muse, varscan2
- FRMPD2 | c.2901C>T p.G967= | Silent (SNP) | VAF 59/400 reads (15%) | catalogued as COSV100564288; called by muse, mutect2, varscan2
- FZD6 | c.987T>G p.A329= | Silent (SNP) | VAF 58/124 reads (47%) | catalogued as COSV100708519; called by muse, varscan2
- GAD2 | c.84C>A p.A28= | Silent (SNP) | VAF 23/113 reads (20%) | catalogued as COSV99394211; called by muse, mutect2, varscan2
- GATAD2A | c.1299C>T p.S433= | Silent (SNP) | VAF 13/64 reads (20%) | catalogued as rs367577231; called by muse, mutect2, varscan2
- GIGYF1 | c.1794A>G p.P598= | Silent (SNP) | VAF 11/24 reads (46%) | catalogued as rs758328622, COSV51939172; called by muse, varscan2
- GPR34 | c.90C>T p.S30= | Silent (SNP) | VAF 14/40 reads (35%) | catalogued as rs781610719, COSV100587868, COSV59365337; called by muse, mutect2, varscan2
- GPR6 | c.717C>T p.G239= | Silent (SNP) | VAF 6/23 reads (26%) | catalogued as COSV99254620; called by muse, mutect2
- GRID1 | c.1137G>T p.G379= | Silent (SNP) | VAF 20/43 reads (47%) | catalogued as COSV100027004; called by muse, mutect2, varscan2
- GRM1 | c.3471G>A p.S1157= | Silent (SNP) | VAF 8/35 reads (23%) | catalogued as rs767868364, COSV51381921, COSV99269556; called by muse, mutect2, varscan2
- H4C7 | c.210C>T p.A70= | Silent (SNP) | VAF 35/70 reads (50%) | catalogued as rs772455445, COSV55101229; called by muse, mutect2, varscan2
- HERPUD2 | c.984T>C p.H328= | Silent (SNP) | VAF 13/53 reads (25%) | catalogued as COSV100258168; called by muse, mutect2, varscan2
- HHLA2 | c.171C>T p.S57= | Silent (SNP) | VAF 27/92 reads (29%) | catalogued as rs370821029; called by muse, mutect2, varscan2
- HIVEP2 | c.4551G>A p.S1517= | Silent (SNP) | VAF 29/67 reads (43%) | catalogued as rs886762722, COSV99176378; called by muse, mutect2, varscan2
- HIVEP2 | c.3369G>A p.P1123= | Silent (SNP) | VAF 24/68 reads (35%) | catalogued as rs372386907; called by muse, varscan2
- HMCN1 | c.15696C>T p.N5232= | Silent (SNP) | VAF 4/42 reads (10%) | catalogued as rs374629223; called by mutect2, varscan2
- IGSF10 | c.5406C>T p.D1802= | Silent (SNP) | VAF 95/141 reads (67%) | catalogued as rs750603029, COSV56784113; called by muse, mutect2, varscan2
- IL11RA | c.405C>T p.S135= | Silent (SNP) | VAF 57/154 reads (37%) | catalogued as COSV99426612; called by muse, mutect2, varscan2
- INSL5 | c.249G>A p.P83= | Silent (SNP) | VAF 26/55 reads (47%) | catalogued as rs776464414, COSV58787894; called by muse, mutect2, varscan2
- IRX6 | c.180G>A p.A60= | Silent (SNP) | VAF 19/48 reads (40%) | catalogued as rs748112787, COSV51860899; called by muse, mutect2, varscan2
- ITGAE | c.1122G>A p.A374= | Silent (SNP) | VAF 56/124 reads (45%) | catalogued as rs1185761206, COSV53994655; called by muse, mutect2, varscan2
- KCNJ9 | c.342C>A p.S114= | Silent (SNP) | VAF 36/243 reads (15%) | catalogued as COSV63632370; called by muse, mutect2, varscan2
- KDM2B | c.1833G>A p.T611= | Silent (SNP) | VAF 38/89 reads (43%) | catalogued as rs782001480, COSV100997700; called by muse, mutect2, varscan2
- KIF18B | c.2136G>A p.P712= (on ENST00000593135 / NM_001265577.2; = p.P724= on NM_001264573.2) | Silent (SNP) | VAF 26/67 reads (39%) | catalogued as rs200703182, COSV59271778; called by muse, mutect2, varscan2
- KMT2A | c.891A>G p.V297= | Silent (SNP) | VAF 9/22 reads (41%) | catalogued as COSV100630153; called by muse, mutect2, varscan2
- KRT12 | c.708C>T p.R236= | Silent (SNP) | VAF 43/107 reads (40%) | catalogued as COSV52432785; called by muse, mutect2, varscan2
- KXD1 | c.522G>T p.T174= | Silent (SNP) | VAF 15/61 reads (25%) | catalogued as COSV99723756; called by muse, mutect2, varscan2
- L3MBTL2 | c.87C>T p.G29= | Silent (SNP) | VAF 24/121 reads (20%) | catalogued as COSV99346238; called by muse, mutect2, varscan2
- LAMA3 | c.3786C>T p.G1262= | Silent (SNP) | VAF 10/31 reads (32%) | catalogued as rs752958608, COSV58063426; called by muse, mutect2, varscan2
- LAPTM4A | c.696T>C p.P232= | Silent (SNP) | VAF 17/33 reads (52%) | catalogued as COSV99442586; called by muse, mutect2, varscan2
- LIPG | c.519C>T p.H173= | Silent (SNP) | VAF 34/65 reads (52%) | catalogued as rs139830474; called by muse, mutect2, varscan2
- MAK | c.63C>T p.G21= | Silent (SNP) | VAF 21/63 reads (33%) | catalogued as COSV100504738, COSV57568398; called by muse, mutect2, varscan2
- METTL14 | c.1329G>T p.G443= | Silent (SNP) | VAF 23/33 reads (70%) | catalogued as COSV101183426; called by muse, mutect2, varscan2
- MICALL2 | c.2316C>T p.D772= | Silent (SNP) | VAF 10/41 reads (24%) | catalogued as rs377450726; called by muse, mutect2, varscan2
- MMP15 | c.1761G>A p.A587= | Silent (SNP) | VAF 7/48 reads (15%) | catalogued as rs748897402, COSV99539792; called by muse, mutect2, varscan2
- MMP17 | c.1179C>T p.S393= | Silent (SNP) | VAF 9/22 reads (41%) | catalogued as rs200341756, COSV62179405; called by muse, mutect2
- MPP7 | c.207C>T p.L69= | Silent (SNP) | VAF 8/22 reads (36%) | catalogued as COSV100518037; called by muse, mutect2, varscan2
- MUC5B | c.15690C>T p.D5230= | Silent (SNP) | VAF 10/57 reads (18%) | catalogued as rs368888615, COSV101500893; called by muse, mutect2, varscan2
- MYEF2 | c.1320T>C p.I440= | Silent (SNP) | VAF 15/32 reads (47%) | catalogued as COSV99982269; called by muse, mutect2, varscan2
- MYH15 | c.4482C>G p.L1494= | Silent (SNP) | VAF 19/85 reads (22%) | catalogued as COSV99844519; called by muse, mutect2, varscan2
- MYOM2 | c.684A>C p.S228= | Silent (SNP) | VAF 9/37 reads (24%) | catalogued as rs1423022189, COSV100038637; called by muse, mutect2, varscan2
- MYOM3 | c.267C>A p.T89= | Silent (SNP) | VAF 41/91 reads (45%) | catalogued as rs1375528023, COSV58398486; called by muse, mutect2, varscan2
- MYT1L | c.3015C>T p.C1005= | Silent (SNP) | VAF 30/59 reads (51%) | catalogued as COSV101217482; called by muse, mutect2, varscan2
- NAV3 | c.4149T>C p.H1383= | Silent (SNP) | VAF 21/41 reads (51%) | catalogued as COSV99896547; called by muse, mutect2, varscan2
- NF2 | c.1698C>T p.S566= | Silent (SNP) | VAF 10/22 reads (45%) | catalogued as rs751987156, COSV58519572; ClinVar: likely benign; called by muse, mutect2, varscan2
- NFATC1 | c.1695C>T p.R565= | Silent (SNP) | VAF 18/55 reads (33%) | catalogued as COSV53698094; called by muse, mutect2, varscan2
- NFKB1 | c.711C>T p.D237= (on ENST00000394820 / NM_001382627.1; = p.D238= on NM_003998.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 26/70 reads (37%) | catalogued as rs571565278, COSV99897997; called by muse, mutect2, varscan2
- NR4A1 | c.1035G>A p.R345= | Silent (SNP) | VAF 25/52 reads (48%) | catalogued as COSV99671853; called by muse, mutect2, varscan2
- NT5C1B | c.456G>A p.T152= (on ENST00000359846 / NM_001199086.2; = p.T92= on NM_033253.4) | Silent (SNP) | VAF 51/132 reads (39%) | catalogued as rs746666603, COSV58396397; called by muse, mutect2, varscan2
- NTN4 | c.204G>A p.T68= | Silent (SNP) | VAF 48/100 reads (48%) | catalogued as rs371848057, COSV100643765; called by muse, mutect2, varscan2
- OR13C4 | c.288A>T p.G96= | Silent (SNP) | VAF 31/74 reads (42%) | catalogued as COSV99470332; called by muse, mutect2, varscan2
- OSBPL3 | c.1524G>A p.A508= | Silent (SNP) | VAF 15/62 reads (24%) | catalogued as rs191769832, COSV57658133; called by muse, mutect2, varscan2
- OSBPL3 | c.819C>T p.H273= | Silent (SNP) | VAF 11/50 reads (22%) | catalogued as rs750277364, COSV100514649, COSV57662684; called by muse, mutect2, varscan2
- P3H3 | c.1441C>T p.L481= | Silent (SNP) | VAF 14/54 reads (26%) | catalogued as COSV51837004; called by muse, mutect2, varscan2
- PARP4 | c.1581C>T p.Y527= | Silent (SNP) | VAF 6/37 reads (16%) | catalogued as rs201085379, COSV101132138; called by muse, mutect2, varscan2
- PAX2 | c.663G>A p.L221= | Silent (SNP) | VAF 52/126 reads (41%) | catalogued as COSV100695484, COSV62290940; called by muse, mutect2, varscan2
- PCDHA7 | c.2247A>G p.S749= | Silent (SNP) | VAF 24/76 reads (32%) | catalogued as COSV100971104; called by muse, mutect2, varscan2
- PCED1B | c.252C>T p.S84= | Silent (SNP) | VAF 9/22 reads (41%) | catalogued as rs754847732, COSV71395457; called by muse, mutect2, varscan2
- PCLO | c.10125C>T p.T3375= | Silent (SNP) | VAF 32/78 reads (41%) | catalogued as rs553676793, COSV61644241; called by muse, mutect2, varscan2
- PDS5A | c.2079G>A p.K693= | Silent (SNP) | VAF 7/12 reads (58%) | catalogued as COSV100337598; called by muse, mutect2, varscan2
- PGK1 | c.210G>A p.V70= | Silent (SNP) | VAF 31/71 reads (44%) | catalogued as rs782224294, COSV64831825; called by muse, mutect2, varscan2
- PI16 | c.6C>T p.H2= | Silent (SNP) | VAF 39/71 reads (55%) | catalogued as rs202171420, COSV101028865; called by muse, mutect2, varscan2
- PIK3CD | c.2967C>T p.L989= | Silent (SNP) | VAF 17/41 reads (41%) | catalogued as COSV100740587, COSV100740600; called by muse, mutect2, varscan2
- PIK3R6 | c.1470C>T p.S490= | Silent (SNP) | VAF 52/120 reads (43%) | catalogued as COSV100266997; called by muse, mutect2, varscan2
- PKD1 | c.633C>T p.S211= | Silent (SNP) | VAF 14/48 reads (29%) | catalogued as rs1049233387, COSV99239266; called by muse, mutect2, varscan2
- PLEKHG5 | c.1563C>A p.P521= (on ENST00000400915 / NM_001042663.3; = p.P484= on NM_020631.6) | Silent (SNP) | VAF 12/24 reads (50%) | catalogued as COSV100557215; called by muse, mutect2, varscan2
- PLOD1 | c.114C>T p.T38= | Silent (SNP) | VAF 37/101 reads (37%) | catalogued as rs11553679, COSV99538997; ClinVar: likely benign; called by muse, mutect2, varscan2
- PRRT2 | c.912C>T p.D304= | Silent (SNP) | VAF 28/72 reads (39%) | catalogued as rs759633234, COSV54882291, COSV99569199; ClinVar: likely benign / conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- PTPRO | c.2208G>A p.Q736= | Silent (SNP) | VAF 23/51 reads (45%) | catalogued as COSV99841990; called by muse, mutect2, varscan2
- RASL10A | c.546G>A p.A182= | Silent (SNP) | VAF 27/50 reads (54%) | catalogued as rs955373151, COSV99329753; called by muse, mutect2, varscan2
- RASSF7 | c.915G>A p.P305= | Silent (SNP) | VAF 18/41 reads (44%) | catalogued as rs150125797; called by muse, mutect2, varscan2
- RBBP8NL | c.1665C>T p.D555= | Silent (SNP) | VAF 81/189 reads (43%) | catalogued as rs747228572, COSV99437056; called by muse, mutect2, varscan2
- RBM10 | c.1044C>T p.I348= | Silent (SNP) | VAF 22/45 reads (49%) | catalogued as COSV100238407; called by muse, mutect2, varscan2
- RBM19 | c.1863C>T p.G621= | Silent (SNP) | VAF 23/55 reads (42%) | catalogued as rs746684907, COSV99926939; called by muse, mutect2, varscan2
- RPRD2 | c.2976C>T p.G992= | Silent (SNP) | VAF 12/76 reads (16%) | catalogued as rs587663000, COSV64819123; called by muse, mutect2, varscan2
- RPS6KC1 | c.2205G>A p.R735= | Silent (SNP) | VAF 15/39 reads (38%) | catalogued as COSV100874127; called by muse, mutect2, varscan2
- SAMD11 | c.609C>T p.S203= | Silent (SNP) | VAF 18/119 reads (15%) | catalogued as COSV100498218; called by muse, mutect2, varscan2
- SEL1L | c.2139C>T p.G713= | Silent (SNP) | VAF 13/40 reads (33%) | catalogued as rs765245803, COSV60919603; called by muse, mutect2, varscan2
- SERPINC1 | c.882C>T p.R294= | Silent (SNP) | VAF 29/79 reads (37%) | catalogued as rs184508490, COSV100875129; called by muse, mutect2, varscan2
- SF3B1 | c.3513G>A p.P1171= | Silent (SNP) | VAF 26/45 reads (58%) | catalogued as rs1342839967, COSV100135222; called by muse, mutect2, varscan2
- SHCBP1L | c.1524A>C p.T508= | Silent (SNP) | VAF 16/53 reads (30%) | catalogued as COSV100841112; called by muse, mutect2, varscan2
- SIGLEC1 | c.2190C>T p.N730= | Silent (SNP) | VAF 39/79 reads (49%) | catalogued as rs186364499, COSV99171457; called by muse, mutect2, varscan2
- SIT1 | c.72C>T p.G24= | Silent (SNP) | VAF 19/39 reads (49%) | catalogued as rs775500239, COSV99425835; called by muse, mutect2, varscan2
54 further variants in this file (0 protein-altering or splice-affecting, 39 silent, 15 other) are not listed here.
